Somatic mutation profile of tumor specimen TCGA-A5-A0GB-01A (aliquot TCGA-A5-A0GB-01A-11W-A062-09) from TCGA case TCGA-A5-A0GB, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 65.4 years (23,883 days).
Specimen TCGA-A5-A0GB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b67dbbab-42a6-46ab-84ef-70dd9c6eecef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A0GB-10A (Blood Derived Normal), aliquot TCGA-A5-A0GB-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ada36f4e-0fa0-4e43-85be-e6da38b43ba2

The open-access MAF lists 846 somatic variants for this specimen: 638 protein-altering or splice-affecting, 187 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 423, Silent 187, Frame Shift Del 140, Nonsense Mutation 26, Frame Shift Ins 25, Splice Site 13, 3'UTR 8, Intron 8, Splice Region 6, In Frame Del 4, 5'UTR 2, 5'Flank 2.

Variants (750 of 846; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5012del p.N1671Ifs*4 (on ENST00000272895 / NM_173076.3; = p.N1353Ifs*4 on NM_015657.3) | Frame Shift Del (DEL) | VAF 29/90 reads (32%) | catalogued as rs387906285, CD051281; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 23/58 reads (40%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- ARSA | c.684+1G>A p.X228_splice | Splice Site (SNP) | VAF 15/30 reads (50%) | catalogued as rs146371968, CS951348, COSV99332390; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 29/93 reads (31%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CHRNA4 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as rs281865068, CM094469, COSV64719406; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CREBBP | c.1669del p.A557Pfs*5 | Frame Shift Del (DEL) | VAF 30/93 reads (32%) | catalogued as rs398124139, COSV52114376; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FERMT1 | c.1161del p.A388Lfs*14 | Frame Shift Del (DEL) | VAF 30/97 reads (31%) | catalogued as rs869312729, CD040332; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 16/43 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIGO | c.2191del p.R731Vfs*17 | Frame Shift Del (DEL) | VAF 30/77 reads (39%) | catalogued as rs760848629; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 84/212 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs886042002, CM162636, COSV55873442, COSV55926654, COSV55949642; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.635-1G>T p.X212_splice | Splice Site (SNP) | VAF 331/373 reads (89%) | hotspot (GDC flag); catalogued as rs876661024, CS090867, CS993675, COSV64289221, COSV64292432, COSV64296169; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.4786C>T p.R1596C (on ENST00000303395 / NM_001202435.3; = p.R1585C on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/139 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121917993, CM071991, COSV57683326; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- UGT1A1 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 122/305 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139607673, CM983520; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.3881G>A p.R1294H | Missense Mutation (SNP) | VAF 150/344 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as rs774156655, COSV62323560; called by muse, mutect2, varscan2
- ABHD6 | c.1007T>C p.L336P | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.276); catalogued as COSV55910539; called by muse, mutect2, varscan2
- ABL1 | c.1765C>T p.R589C | Missense Mutation (SNP) | VAF 61/146 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs754252285, COSV59330032; called by muse, mutect2, varscan2
- ACACB | c.4511G>A p.R1504Q | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs549887432, COSV58147231; called by muse, mutect2, varscan2
- ACTG1 | c.653A>G p.Y218C | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV59512151; called by muse, mutect2, varscan2
- ACTN2 | c.2090G>T p.G697V | Missense Mutation (SNP) | VAF 119/425 reads (28%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV63978465; called by muse, mutect2, varscan2
- ACVR1 | c.752T>C p.L251S | Missense Mutation (SNP) | VAF 168/384 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.25); catalogued as COSV55123107; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 110/259 reads (42%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM10 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as rs752797397, COSV53048879; called by muse, mutect2, varscan2
- ADAM29 | c.901G>T p.G301* | Nonsense Mutation (SNP) | VAF 160/362 reads (44%) | catalogued as COSV63668604; called by muse, varscan2
- ADAMTS20 | c.2355del p.E786Kfs*86 | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | catalogued as rs1177283960; called by mutect2, pindel, varscan2
- ADAT2 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 82/190 reads (43%) | catalogued as rs773519162, COSV52793296; called by muse, mutect2, varscan2
- ADCY3 | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 111/292 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs750756120, COSV53167126; called by muse, mutect2, varscan2
- ADGRE3 | c.762del p.F254Lfs*12 | Frame Shift Del (DEL) | VAF 112/296 reads (38%) | catalogued as rs762974450; called by mutect2, pindel, varscan2
- AFAP1L1 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as rs375742704; called by muse, mutect2, varscan2
- AGO3 | c.1453C>T p.P485S | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.177); catalogued as COSV55797397; called by muse, mutect2, varscan2
- AGRN | c.2903C>T p.P968L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.274); catalogued as rs772386655, COSV65072478; called by muse, mutect2
- AKAP12 | c.3933A>C p.E1311D | Missense Mutation (SNP) | VAF 194/447 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV53582529; called by muse, mutect2, varscan2
- AKAP13 | c.4013C>A p.P1338H | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV63470599; called by muse, mutect2, varscan2
- AKAP3 | c.1772G>T p.R591M | Missense Mutation (SNP) | VAF 108/281 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV57415886, COSV57420926; called by muse, mutect2, varscan2
- ALDH2 | c.864del p.K289Rfs*122 | Frame Shift Del (DEL) | VAF 19/62 reads (31%) | catalogued as rs771889973, COSV55672572; called by mutect2, pindel, varscan2
- ALPK2 | c.4451C>A p.P1484H | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV64497438; called by muse, mutect2, varscan2
- ANKRD35 | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs782239839, COSV62911666; called by muse, mutect2, varscan2
- ANLN | c.926G>A p.C309Y | Missense Mutation (SNP) | VAF 80/189 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV56073589, COSV56079681; called by muse, mutect2, varscan2
- ANO4 | c.1306G>A p.V436I (on ENST00000392977 / NM_001286615.2; = p.V401I on NM_178826.4) | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV54614393; called by muse, mutect2, varscan2
- ANO4 | c.2284T>C p.S762P (on ENST00000392977 / NM_001286615.2; = p.S727P on NM_178826.4) | Missense Mutation (SNP) | VAF 93/190 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV54614401; called by muse, mutect2, varscan2
- APC | c.8141G>A p.R2714H | Missense Mutation (SNP) | VAF 130/280 reads (46%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs747362422, COSV57335133; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- APEX2 | c.1393C>T p.R465C | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as rs764409927, COSV58193466; called by muse, mutect2, varscan2
- APOL1 | c.680C>T p.T227I | Missense Mutation (SNP) | VAF 94/248 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59869932; called by muse, mutect2
- ARHGAP20 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 141/361 reads (39%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV52819618; called by muse, mutect2, varscan2
- ARHGAP36 | c.1388G>A p.R463H | Missense Mutation (SNP) | VAF 173/403 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV52263795; called by muse, mutect2, varscan2
- ARID1A | c.1213C>T p.Q405* | Nonsense Mutation (SNP) | VAF 131/326 reads (40%) | catalogued as COSV61389661; called by muse, mutect2, varscan2
- ARMC5 | c.2377C>T p.R793* | Nonsense Mutation (SNP) | VAF 5/11 reads (45%) | catalogued as rs1489499125, COSV51660192; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.626del p.N209Ifs*9 | Frame Shift Del (DEL) | VAF 258/662 reads (39%) | catalogued as rs1295666772; called by mutect2, varscan2
- ARRDC3 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 30/67 reads (45%) | catalogued as rs759916739, COSV54366081; called by muse, mutect2, varscan2
- ASB16 | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs368482999; called by muse, mutect2, varscan2
- ASCC3 | c.5284C>T p.R1762C | Missense Mutation (SNP) | VAF 78/191 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138910225, COSV64981462; called by muse, mutect2, varscan2
- ASTE1 | c.795T>G p.H265Q | Missense Mutation (SNP) | VAF 68/159 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53910671; called by muse, mutect2, varscan2
- ATF3 | c.505C>A p.L169I | Missense Mutation (SNP) | VAF 67/238 reads (28%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.987); catalogued as COSV54237354; called by muse, mutect2, varscan2
- ATM | c.6007-2A>G p.X2003_splice | Splice Site (SNP) | VAF 39/76 reads (51%) | catalogued as COSV53776522; called by muse, mutect2, varscan2
- ATP10A | c.3749C>T p.A1250V | Missense Mutation (SNP) | VAF 84/174 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs146387652; called by muse, mutect2, varscan2
- ATP8A2 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1383273159, COSV54949269; called by muse, mutect2, varscan2
- ATP8A2 | c.1745C>T p.T582I | Missense Mutation (SNP) | VAF 188/504 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.649); catalogued as rs1394549747, COSV54977629; called by muse, varscan2
- ATP8B4 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as rs182947621, COSV52724885; called by muse, mutect2, varscan2
- B4GALT3 | c.1069T>C p.Y357H | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.03); catalogued as rs779461856, COSV60528150; called by muse, mutect2, varscan2
- B4GALT3 | c.794T>G p.I265S | Missense Mutation (SNP) | VAF 165/527 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60528160; called by muse, mutect2, varscan2
- BABAM2 | c.488del p.N163Tfs*13 | Frame Shift Del (DEL) | VAF 77/174 reads (44%) | catalogued as COSV59620972; called by mutect2, varscan2
- BBS9 | c.826C>G p.Q276E | Missense Mutation (SNP) | VAF 111/281 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.155); catalogued as COSV54188467; called by muse, mutect2, varscan2
- BCL6B | c.1323+1G>A p.X441_splice | Splice Site (SNP) | VAF 35/82 reads (43%) | catalogued as rs1043446742, COSV53430350; called by muse, mutect2, varscan2
- BCLAF3 | c.1978C>T p.P660S (on ENST00000379682 / NM_001367774.1; = p.P631S on NM_198279.3) | Missense Mutation (SNP) | VAF 48/464 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.05); catalogued as COSV61415149; called by muse, mutect2, varscan2
- BOC | c.2270G>A p.S757N | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56358363; called by muse, mutect2, varscan2
- BRD8 | c.2250-3del | Splice Region (DEL) | VAF 78/180 reads (43%) | catalogued as rs749043197; called by mutect2, varscan2
- BRINP2 | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs769910100, COSV64180475; called by muse, mutect2, varscan2
- BRINP3 | c.1519C>T p.R507* | Nonsense Mutation (SNP) | VAF 131/410 reads (32%) | catalogued as COSV100818702, COSV66515003; called by muse, mutect2, varscan2
- BRINP3 | c.562A>G p.R188G | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66542124; called by muse, mutect2, varscan2
- C16orf78 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs373637026, COSV54558555; called by muse, mutect2, varscan2
- C1orf112 | c.2093C>T p.A698V | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV53682948; called by muse, mutect2, varscan2
- CACNA1C | c.4147G>T p.G1383W | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59775065; called by muse, mutect2, varscan2
- CACNA1F | c.1108G>A p.V370I | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs782458308, COSV59907127; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAD | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 8/155 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs918097614, COSV53032195; called by muse, mutect2
- CAMTA2 | c.2417C>T p.A806V | Missense Mutation (SNP) | VAF 75/174 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as rs868801244, COSV52776827; called by muse, mutect2, varscan2
- CAP2 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 111/281 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.307); catalogued as COSV57731034, COSV57737344; called by muse, mutect2, varscan2
- CASD1 | c.1626del p.A543Qfs*13 | Frame Shift Del (DEL) | VAF 36/87 reads (41%) | catalogued as rs770159446; called by mutect2, varscan2
- CAST | c.1335A>T p.E445D (on ENST00000341926; = p.E528D on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV57789789; called by muse, mutect2, varscan2
- CCDC15 | c.581del p.K194Rfs*29 | Frame Shift Del (DEL) | VAF 24/54 reads (44%) | catalogued as rs759789184, COSV99049086; called by mutect2, varscan2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 33/119 reads (28%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC191 | c.301A>G p.T101A | Missense Mutation (SNP) | VAF 90/224 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV55676619; called by muse, mutect2, varscan2
- CCDC22 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs782815473, COSV66109686; called by muse, varscan2
- CCDC54 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 60/402 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53759935; called by muse, mutect2, varscan2
- CCDC80 | c.1658del p.K553Rfs*2 | Frame Shift Del (DEL) | VAF 82/202 reads (41%) | catalogued as rs1253078189; called by mutect2, varscan2
- CCL7 | c.38C>T p.T13I | Missense Mutation (SNP) | VAF 78/165 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV52337309; called by muse, mutect2, varscan2
- CD163L1 | c.186G>T p.E62D | Missense Mutation (SNP) | VAF 167/375 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58025168; called by muse, mutect2, varscan2
- CD74 | c.770G>A p.G257D | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50534717; called by muse, mutect2
- CDC14A | c.679C>G p.L227V | Missense Mutation (SNP) | VAF 78/204 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60563807; called by muse, mutect2, varscan2
- CDK9 | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV64724229; called by muse, mutect2, varscan2
- CELSR3 | c.3176A>G p.D1059G | Missense Mutation (SNP) | VAF 97/214 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51156345; called by muse, mutect2, varscan2
- CEP162 | c.2849C>T p.A950V | Missense Mutation (SNP) | VAF 104/249 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57624908; called by muse, mutect2, varscan2
- CETP | c.859T>G p.F287V | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as rs745468187, COSV52364444; called by muse, mutect2, varscan2
- CFAP100 | c.530C>T p.T177M | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs142359829; called by muse, mutect2, varscan2
- CFAP45 | c.1631T>C p.I544T | Missense Mutation (SNP) | VAF 164/613 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV63651188; called by muse, mutect2, varscan2
- CHD3 | c.107A>G p.D36G | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.114); catalogued as COSV57880631; called by muse, mutect2, varscan2
- CHD5 | c.5122G>A p.A1708T | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1318894130, COSV52408677; called by muse, mutect2, varscan2
- CHD5 | c.2824G>A p.A942T | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.492); catalogued as rs748825072, COSV52425558; called by muse, mutect2, varscan2
- CHML | c.1595C>T p.P532L | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.067); catalogued as rs755671388, COSV59366569; called by muse, mutect2, varscan2
- CIITA | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 59/132 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as rs901729238, COSV60861021, COSV60862314; called by muse, mutect2, varscan2
- CLASRP | c.1894_1898del p.K632Efs*61 | Frame Shift Del (DEL) | VAF 5/23 reads (22%) | catalogued as COSV55519555; called by mutect2, pindel, varscan2
- CLDN18 | c.13A>G p.T5A | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV51738160; called by muse, mutect2, varscan2
- CLEC16A | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 94/209 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1164581981, COSV68502114; called by muse, mutect2, varscan2
- CLEC2B | c.73G>T p.V25F | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.3); catalogued as COSV57310725; called by muse, mutect2, varscan2
- CLEC9A | c.278T>C p.M93T | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs148035230; called by muse, mutect2, varscan2
- CMKLR1 | c.712G>A p.A238T (on ENST00000312143 / NM_001142344.2; = p.A236T on NM_004072.3) | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.071); catalogued as rs767660173, COSV56442059; called by muse, mutect2, varscan2
- CMYA5 | c.10903G>A p.A3635T | Missense Mutation (SNP) | VAF 158/353 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1348347054, COSV71409663; called by muse, mutect2, varscan2
- CNOT10 | c.337T>C p.Y113H | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.556); catalogued as COSV100094640, COSV59395466; called by muse, mutect2, varscan2
- CNOT11 | c.368A>G p.Q123R | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs1440844221, COSV56821149; called by muse, mutect2
- CNOT6 | c.491-2A>G p.X164_splice | Splice Site (SNP) | VAF 78/172 reads (45%) | catalogued as COSV56164165; called by muse, mutect2
- CNOT6 | c.491T>A p.I164N | Missense Mutation (SNP) | VAF 78/172 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV56164171; called by muse, mutect2
- CNPPD1 | c.573-2A>T p.X191_splice | Splice Site (SNP) | VAF 28/74 reads (38%) | catalogued as COSV55409658; called by muse, mutect2, varscan2
- CNPY3 | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 63/133 reads (47%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.993); catalogued as rs755208427, COSV65710094; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 52/108 reads (48%) | catalogued as rs374805044; called by mutect2, varscan2
- COL25A1 | c.1559C>G p.P520R | Missense Mutation (SNP) | VAF 236/534 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67651872, COSV67659389; called by muse, mutect2, varscan2
- COLEC11 | c.72T>A p.H24Q | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.035); catalogued as COSV52592808, COSV52598096; called by muse, mutect2, varscan2
- COPA | c.3380G>A p.R1127H | Missense Mutation (SNP) | VAF 86/306 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs776528615, COSV54109896; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COPB2 | c.2717A>G p.D906G | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as COSV60351325; called by muse, mutect2, varscan2
- COQ6 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 122/242 reads (50%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as COSV53180284; called by muse, mutect2
- COQ8B | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760868849, COSV54685573; called by muse, mutect2, varscan2
- CPAMD8 | c.2917C>T p.R973C (on ENST00000651564; = p.R926C on NM_015692.5) | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs780318960, COSV71597410; called by muse, mutect2, varscan2
- CPT1B | c.651del p.R218Gfs*17 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | catalogued as rs1433021617; called by mutect2, pindel
- CPXM2 | c.829T>G p.S277A | Missense Mutation (SNP) | VAF 76/152 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV53864829, COSV53871457; called by muse, mutect2, varscan2
- CSTF2 | c.1720A>T p.T574S | Missense Mutation (SNP) | VAF 60/284 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV65890595; called by muse, varscan2
- CTBS | c.962C>A p.P321H | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.077); catalogued as COSV55364863; called by muse, mutect2, varscan2
- CTPS1 | c.62G>A p.S21N | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65454193; called by muse, mutect2, varscan2
- CUL9 | c.2875C>A p.P959T | Missense Mutation (SNP) | VAF 160/367 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.316); catalogued as COSV52735139; called by muse, mutect2, varscan2
- CXXC5 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs373316102; called by muse, mutect2, varscan2
- CYP27A1 | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs370868184; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCUN1D4 | c.476A>G p.Q159R | Missense Mutation (SNP) | VAF 76/179 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV58125269; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 86/222 reads (39%) | catalogued as rs766714372; called by mutect2, varscan2
- DIAPH1 | c.2912A>T p.E971V | Missense Mutation (SNP) | VAF 246/591 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as COSV53889016; called by muse, mutect2, varscan2
- DMD | c.1145A>G p.H382R | Missense Mutation (SNP) | VAF 110/259 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55902791; called by muse, mutect2, varscan2
- DMRT2 | c.902A>T p.N301I | Missense Mutation (SNP) | VAF 159/327 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as COSV52403149; called by muse, mutect2, varscan2
- DMXL1 | c.2649C>G p.H883Q | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV60721286; called by muse, mutect2, varscan2
- DMXL2 | c.326del p.L109* | Frame Shift Del (DEL) | VAF 25/50 reads (50%) | catalogued as rs752363479; called by mutect2, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 42/93 reads (45%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAH5 | c.12076G>A p.E4026K | Missense Mutation (SNP) | VAF 54/212 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs776854779, COSV54239439; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNHD1 | c.13594C>T p.R4532C | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as rs1453485435, COSV54432610; called by muse, mutect2, varscan2
- DOCK1 | c.3463G>A p.E1155K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV54761193; called by muse, mutect2, varscan2
- DOCK11 | c.3041C>T p.A1014V | Missense Mutation (SNP) | VAF 114/225 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs759590551, COSV52246739; called by muse, mutect2, varscan2
- DOCK5 | c.4033del p.R1345Gfs*12 | Frame Shift Del (DEL) | VAF 9/40 reads (23%) | catalogued as rs1239294263; called by mutect2, pindel
- DOCK8 | c.3339del p.F1113Lfs*2 | Frame Shift Del (DEL) | VAF 21/49 reads (43%) | catalogued as rs748134881; called by mutect2, varscan2
- DPPA5 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as COSV64875337; called by muse, mutect2, varscan2
- DSC3 | c.2486T>G p.L829R | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1192011991, COSV64574883, COSV64575609; called by muse, mutect2, varscan2
- DYNC1I2 | c.105del p.E36Kfs*34 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | catalogued as rs755197346; called by mutect2, varscan2
- EDC4 | c.3852G>A p.A1284= | Splice Region (SNP) | VAF 145/295 reads (49%) | catalogued as rs371474948; called by muse, mutect2, varscan2
- EFR3A | c.1544T>A p.I515N | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV54462614; called by muse, mutect2, varscan2
- ELOA2 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as rs974032541, COSV55308374, COSV55309189; called by muse, mutect2, varscan2
- EMX2 | c.707T>A p.I236N | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.167); catalogued as COSV71294866; called by muse, mutect2, varscan2
- ENO3 | c.1099del p.V367* | Frame Shift Del (DEL) | VAF 39/117 reads (33%) | catalogued as rs961001512; called by mutect2, pindel, varscan2
- EPHA5 | c.1205C>A p.A402E | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.122); catalogued as COSV56675865; called by muse, mutect2, varscan2
- EPHX2 | c.599C>T p.T200I | Missense Mutation (SNP) | VAF 68/153 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.742); catalogued as COSV66846153; called by muse, mutect2, varscan2
- EPX | c.953A>C p.E318A | Missense Mutation (SNP) | VAF 81/225 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV56599543; called by muse, mutect2, varscan2
- ERAP1 | c.1625T>C p.V542A | Missense Mutation (SNP) | VAF 69/210 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV57091569; called by muse, mutect2
- ETAA1 | c.1919A>G p.N640S | Missense Mutation (SNP) | VAF 149/325 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as rs775659371, COSV55475311; called by muse, mutect2, varscan2
- EXOSC10 | c.2572dup p.I858Nfs*2 (on ENST00000376936 / NM_001001998.3; = p.I833Nfs*2 on NM_002685.4) | Frame Shift Ins (INS) | VAF 34/84 reads (40%) | catalogued as rs1194058340; called by mutect2, varscan2
- EXT1 | c.146C>A p.P49H | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.201); catalogued as COSV100983749, COSV65485255; called by muse, mutect2, varscan2
- FAM120B | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 92/194 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1433348074, COSV53001764, COSV53008633; called by muse, mutect2, varscan2
- FAM151A | c.416-1G>T p.X139_splice | Splice Site (SNP) | VAF 27/81 reads (33%) | catalogued as COSV56363310; called by muse, mutect2, varscan2
- FASLG | c.242T>C p.L81P | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as COSV60681040; called by muse, mutect2, varscan2
- FAT1 | c.709A>T p.I237F | Missense Mutation (SNP) | VAF 148/348 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as COSV71676120; called by muse, mutect2, varscan2
- FBN2 | c.6412del p.D2138Tfs*111 | Frame Shift Del (DEL) | VAF 96/226 reads (42%) | catalogued as COSV52520596; called by mutect2, pindel, varscan2
- FBXO46 | c.62C>A p.S21* | Nonsense Mutation (SNP) | VAF 17/40 reads (43%) | catalogued as COSV58349887; called by muse, mutect2, varscan2
- FCHSD1 | c.2065C>A p.L689I | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.142); catalogued as COSV51838793; called by muse, mutect2, varscan2
- FGD1 | c.1519C>A p.L507M | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64309725; called by muse, mutect2, varscan2
- FKBP2 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV58588598; called by muse, mutect2, varscan2
- FLNC | c.3344G>A p.G1115D | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57965451; called by muse, mutect2, varscan2
- FMN1 | c.2633del p.P878Lfs*20 (on ENST00000616417 / NM_001277313.2; = p.P655Lfs*20 on NM_001103184.4) | Frame Shift Del (DEL) | VAF 96/219 reads (44%) | catalogued as COSV100568446; called by mutect2, pindel, varscan2
- FMN2 | c.1648C>T p.Q550* | Nonsense Mutation (SNP) | VAF 109/335 reads (33%) | catalogued as COSV60455323; called by muse, mutect2, varscan2
- FMO3 | c.541del p.V181Yfs*31 | Frame Shift Del (DEL) | VAF 29/235 reads (12%) | catalogued as COSV63008665; called by mutect2, pindel, varscan2
- FRAS1 | c.5574dup p.A1859Cfs*3 | Frame Shift Ins (INS) | VAF 24/49 reads (49%) | catalogued as rs753831692; called by mutect2, varscan2
- FUBP3 | c.833A>G p.K278R | Missense Mutation (SNP) | VAF 69/160 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV60516854; called by muse, varscan2
- FXR2 | c.1843A>G p.I615V | Missense Mutation (SNP) | VAF 154/343 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.039); catalogued as COSV51469582; called by muse, mutect2, varscan2
- GABRG3 | c.751A>G p.R251G | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV61534525; called by muse, mutect2, varscan2
- GALNT18 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57158369; called by muse, mutect2, varscan2
- GATB | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs766660548, COSV56133615; called by muse, mutect2, varscan2
- GBE1 | c.1644G>A p.W548* | Nonsense Mutation (SNP) | VAF 26/87 reads (30%) | catalogued as COSV70103114; called by muse, mutect2, varscan2
- GDF5 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as COSV65503644; called by muse, mutect2, varscan2
- GFOD2 | c.772G>T p.G258* | Nonsense Mutation (SNP) | VAF 4/73 reads (5%) | catalogued as COSV52059948; called by muse, mutect2
- GGN | c.809del p.G270Afs*20 | Frame Shift Del (DEL) | VAF 17/40 reads (43%) | catalogued as COSV53057105; called by mutect2, pindel, varscan2
- GHDC | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.55); PolyPhen benign (0.374); catalogued as rs747762581, COSV56989997; called by muse, mutect2, varscan2
- GIGYF2 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 68/161 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1452826937, COSV65246026; called by muse, mutect2, varscan2
- GJB4 | c.724G>T p.G242* | Nonsense Mutation (SNP) | VAF 70/136 reads (51%) | catalogued as COSV58357150; called by muse, mutect2, varscan2
- GLMN | c.62T>G p.F21C | Missense Mutation (SNP) | VAF 75/173 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV64861702; called by muse, mutect2, varscan2
- GLP1R | c.104C>T p.T35M | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.537); catalogued as rs148158586; called by muse, mutect2
- GLRX | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 100/236 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs140804825; called by muse, mutect2, varscan2
- GNB5 | c.910A>G p.T304A (on ENST00000261837 / NM_016194.4; = p.T262A on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/220 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV55901364; called by muse, mutect2, varscan2
- GOLGB1 | c.9528G>T p.E3176D | Missense Mutation (SNP) | VAF 107/247 reads (43%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.47); catalogued as COSV61471306; called by muse, mutect2, varscan2
- GON4L | c.4756C>T p.R1586W | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs369974484; called by muse, mutect2, varscan2
- GOT1 | c.1216C>A p.H406N | Missense Mutation (SNP) | VAF 114/303 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV63203519; called by muse, mutect2, varscan2
- GPR32 | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 85/145 reads (59%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs767962342, COSV54515683; called by muse, mutect2, varscan2
- GRID1 | c.2246C>T p.A749V | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.315); catalogued as COSV60055061; called by muse, mutect2, varscan2
- GRID2 | c.341T>C p.I114T | Missense Mutation (SNP) | VAF 65/128 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56270241; called by muse, mutect2, varscan2
- GRIN3A | c.307C>T p.H103Y | Missense Mutation (SNP) | VAF 2/9 reads (22%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.04); catalogued as COSV62458551; called by muse, mutect2
- GSAP | c.2204T>C p.M735T | Missense Mutation (SNP) | VAF 81/219 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV57533325; called by muse, mutect2, varscan2
- GSDME | c.773del p.L258Rfs*9 | Frame Shift Del (DEL) | VAF 54/174 reads (31%) | catalogued as rs765139282; called by mutect2, pindel, varscan2
- GTF2H4 | c.957G>A p.T319= | Splice Region (SNP) | VAF 15/65 reads (23%) | catalogued as rs149410249; called by muse, mutect2, varscan2
- GYS2 | c.1769A>T p.E590V | Missense Mutation (SNP) | VAF 230/448 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53929151; called by muse, mutect2, varscan2
- H2BC5 | c.20C>A p.S7Y | Missense Mutation (SNP) | VAF 82/176 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.264); catalogued as COSV56803612; called by muse, mutect2, varscan2
- H3C1 | c.247C>A p.L83M | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.823); catalogued as rs772494976, COSV55120641; called by muse, mutect2, varscan2
- HBE1 | c.359G>A p.G120D | Missense Mutation (SNP) | VAF 29/718 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as rs760554801, COSV53081123; called by muse, mutect2
- HEATR1 | c.656T>C p.F219S | Missense Mutation (SNP) | VAF 107/370 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63983121; called by muse, mutect2, varscan2
- HEATR3 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 105/237 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.091); catalogued as COSV53528921; called by muse, mutect2, varscan2
- HEATR5A | c.987del p.F329Lfs*9 | Frame Shift Del (DEL) | VAF 58/150 reads (39%) | catalogued as rs1182843968; called by mutect2, pindel, varscan2
- HECTD1 | c.2306C>T p.A769V | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV67949295; called by muse, mutect2, varscan2
- HERC2 | c.5954T>C p.M1985T | Missense Mutation (SNP) | VAF 92/198 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as rs767191969, COSV55351342; called by muse, mutect2, varscan2
- HERC5 | c.1812del p.F604Lfs*2 | Frame Shift Del (DEL) | VAF 66/167 reads (40%) | catalogued as rs1256699530; called by mutect2, pindel, varscan2
- HFM1 | c.4200del p.F1400Lfs*25 | Frame Shift Del (DEL) | VAF 42/138 reads (30%) | catalogued as rs766204131; called by mutect2, pindel, varscan2
- HIVEP2 | c.44G>T p.R15M | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV50069455; called by muse, mutect2
- HMGB3 | c.573_575del p.E198del | In Frame Del (DEL) | VAF 58/188 reads (31%) | catalogued as rs782325679; called by pindel, varscan2
- HNRNPA2B1 | c.878-2A>G p.X293_splice (on ENST00000354667 / NM_031243.3; = p.X281_splice on NM_002137.4) | Splice Site (SNP) | VAF 71/141 reads (50%) | catalogued as COSV100668215, COSV61158857; called by muse, mutect2, varscan2
- HNRNPL | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.104); catalogued as COSV55495556; called by muse, mutect2
- HPS4 | c.2080G>A p.G694S | Missense Mutation (SNP) | VAF 78/211 reads (37%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.596); catalogued as rs779739799, COSV61105881; called by muse, mutect2, varscan2
- HSD17B4 | c.488T>C p.M163T (on ENST00000414835 / NM_001199291.3; = p.M138T on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 88/206 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56339334; called by muse, mutect2, varscan2
- HTR6 | c.1097T>C p.L366P | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV53877613; called by muse, mutect2, varscan2
- IFT122 | c.2161C>A p.L721I (on ENST00000348417 / NM_052989.3; = p.L662I on NM_018262.4) | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.272); catalogued as COSV56208589; called by muse, mutect2, varscan2
- IFT140 | c.1495T>C p.S499P | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs568075074, COSV68501145; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.60G>T p.Q20H | Missense Mutation (SNP) | VAF 135/483 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1194233882; called by muse, mutect2, varscan2
- IGSF9B | c.1913C>T p.A638V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.217); catalogued as rs1331240078, COSV58073134; called by muse, mutect2, varscan2
- IHO1 | c.1070G>A p.C357Y | Missense Mutation (SNP) | VAF 35/242 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.667); catalogued as rs1191361403, COSV56511215; called by muse, mutect2, varscan2
- IL11RA | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 51/100 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs377108939; called by muse, mutect2, varscan2
- IL21R | c.1549del p.R517Gfs*38 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | catalogued as rs748992699; called by mutect2, pindel, varscan2
- INSRR | c.2378C>T p.A793V | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.118); catalogued as COSV63872607; called by muse, mutect2, varscan2
- INTS1 | c.254C>A p.P85H | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV67179876; called by muse, mutect2, varscan2
- INTS3 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 174/559 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1558001898, COSV59681741; called by muse, mutect2, varscan2
- INTS6L | c.359del p.L120* | Frame Shift Del (DEL) | VAF 39/92 reads (42%) | catalogued as rs782242788; ClinVar: uncertain significance; called by mutect2, varscan2
- ITPKB | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs774932416, COSV55270398, COSV99684322; called by muse, mutect2, varscan2
- JADE3 | c.956C>T p.T319M | Missense Mutation (SNP) | VAF 119/276 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.701); catalogued as rs782548118, COSV54464940; called by muse, mutect2, varscan2
- JAK1 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 145/326 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs1557650255, COSV61096763; called by muse, mutect2, varscan2
- JPH3 | c.1060del p.L354Cfs*117 | Frame Shift Del (DEL) | VAF 5/12 reads (42%) | catalogued as COSV52470301; called by mutect2, varscan2
- KBTBD6 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV65272048; called by muse, mutect2, varscan2
- KCNC1 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554991338, COSV56393455; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNK15 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as rs1379093312, COSV65719796; called by muse, mutect2, varscan2
- KCNMA1 | c.2675C>T p.T892M (on ENST00000286628 / NM_001161352.2; = p.T834M on NM_002247.4) | Missense Mutation (SNP) | VAF 328/724 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.391); catalogued as rs200440843, COSV54269078; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KDM5C | c.202del p.R68Efs*5 | Frame Shift Del (DEL) | VAF 22/66 reads (33%) | catalogued as COSV62890955, COSV62891010; called by mutect2, pindel, varscan2
- KIAA1522 | c.373G>A p.A125T (on ENST00000373480 / NM_001198972.2; = p.A184T on NM_020888.3) | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1308054867, COSV53863000; called by muse, mutect2, varscan2
- KIF1C | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 100/234 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57907627; called by muse, mutect2, varscan2
- KIF21B | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774564420, COSV59762307; called by muse, mutect2, varscan2
- KIF25 | c.344G>A p.S115N | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs374252442; called by muse, mutect2, varscan2
- KIFAP3 | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 17/199 reads (9%) | catalogued as COSV63031043; called by muse, mutect2
- KLC4 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs767962990, COSV52439416; called by muse, mutect2, varscan2
- KLF4 | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65929170; called by muse, mutect2, varscan2
- KLF5 | c.725C>A p.S242Y | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.365); catalogued as COSV66615574; called by muse, mutect2, varscan2
- KLHL1 | c.104del p.G35Efs*31 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as rs749011008; called by mutect2, varscan2
- KPNB1 | c.2591_2592insA p.W864* | Nonsense Mutation (INS) | VAF 72/203 reads (35%) | catalogued as COSV51600754; called by mutect2, pindel*, varscan2
- KRT12 | c.850G>A p.V284I | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1228565509, COSV52432524; called by muse, mutect2, varscan2
- LAMB4 | c.4219G>T p.G1407C | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as rs765269613, COSV52731645; called by muse, mutect2, varscan2
- LAMP2 | c.775A>C p.T259P | Missense Mutation (SNP) | VAF 208/438 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52355439; called by muse, mutect2, varscan2
- LEFTY1 | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV55284156; called by muse, mutect2, varscan2
- LHX4 | c.934del p.Q312Sfs*37 | Frame Shift Del (DEL) | VAF 192/727 reads (26%) | catalogued as rs1396678529; called by mutect2, pindel, varscan2
- LMOD1 | c.1312G>A p.A438T | Missense Mutation (SNP) | VAF 61/203 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.396); catalogued as rs753025774, COSV66172249; called by muse, mutect2, varscan2
- LNX1 | c.602G>A p.G201D (on ENST00000263925 / NM_001126328.3; = p.G105D on NM_032622.2) | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.295); catalogued as COSV55792035; called by muse, mutect2, varscan2
- LRP1 | c.11428C>T p.R3810C | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV54526825; called by muse, mutect2, varscan2
- LRP1B | c.1765G>C p.E589Q | Missense Mutation (SNP) | VAF 107/253 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV67232748; called by muse, mutect2, varscan2
- LRRC66 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 28/324 reads (9%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs774884332, COSV58636950; called by muse, mutect2
- LRTM2 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs776872752, COSV54564421; called by muse, mutect2, varscan2
- LVRN | c.1232A>T p.Y411F | Missense Mutation (SNP) | VAF 89/192 reads (46%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV63498448; called by muse, mutect2, varscan2
- LYPD6B | c.67G>A p.A23T (on ENST00000409029 / NM_001317004.1; = p.A47T on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 127/303 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs369164244; called by muse, mutect2, varscan2
- MAP1B | c.476T>A p.F159Y | Missense Mutation (SNP) | VAF 83/199 reads (42%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.867); catalogued as COSV57106945; called by muse, mutect2, varscan2
- MAP1B | c.6728C>A p.T2243N | Missense Mutation (SNP) | VAF 239/596 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.092); catalogued as rs1190754790, COSV57106350, COSV57106955; called by muse, mutect2, varscan2
- MAP7D1 | c.68del p.P23Qfs*33 | Frame Shift Del (DEL) | VAF 39/128 reads (30%) | catalogued as rs761388884; called by mutect2, varscan2
- MARCHF6 | c.334+1G>A p.X112_splice | Splice Site (SNP) | VAF 59/294 reads (20%) | catalogued as COSV56887284; called by muse, mutect2, varscan2
- MB21D2 | c.577A>G p.S193G | Missense Mutation (SNP) | VAF 81/183 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV66666179; called by muse, mutect2, varscan2
- MBNL2 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.034); catalogued as COSV59126013; called by muse, mutect2, varscan2
- MBNL3 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 112/254 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63731725; called by muse, mutect2, varscan2
- MCM3AP | c.5337del p.F1779Lfs*5 | Frame Shift Del (DEL) | VAF 142/320 reads (44%) | catalogued as COSV52437287; called by mutect2, varscan2
- MDGA1 | c.867G>T p.Q289H | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0.038); catalogued as COSV51802127; called by muse, mutect2, varscan2
- MDN1 | c.1727C>T p.A576V | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV65530687; called by muse, mutect2, varscan2
- MFSD14A | c.806del p.L269Yfs*6 | Frame Shift Del (DEL) | VAF 43/232 reads (19%) | catalogued as rs780635289; called by mutect2, varscan2
- MICAL2 | c.382C>T p.H128Y | Missense Mutation (SNP) | VAF 75/175 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777006718, COSV56326692; called by muse, mutect2, varscan2
- MLPH | c.1744G>A p.A582T | Missense Mutation (SNP) | VAF 89/195 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs201605694, COSV52824324; called by muse, mutect2, varscan2
- MMACHC | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 114/255 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs564280688, COSV53115111; called by muse, mutect2, varscan2
- MMP10 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54247913; called by muse, mutect2, varscan2
- MOCS1 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs756158164, COSV57935540; called by muse, mutect2, varscan2
- MOK | c.795G>T p.M265I | Missense Mutation (SNP) | VAF 77/179 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as COSV51967813; called by muse, mutect2, varscan2
- MPP5 | c.1466A>C p.N489T | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV55532940; called by muse, mutect2, varscan2
- MROH2B | c.3557G>T p.R1186M | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV68189756; called by muse, mutect2
- MRPL10 | c.140T>G p.L47R | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV51621375; called by muse, mutect2, varscan2
- MRPL34 | c.22C>A p.L8M | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.125); catalogued as COSV53113456; called by muse, mutect2, varscan2
- MRPL37 | c.817G>A p.V273M | Missense Mutation (SNP) | VAF 35/243 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.055); catalogued as COSV60322844; called by muse, mutect2, varscan2
- MTNR1B | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 111/247 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763511406, COSV57066837, COSV57069785; called by muse, mutect2, varscan2
- MTR | c.1966G>T p.G656* | Nonsense Mutation (SNP) | VAF 82/272 reads (30%) | catalogued as COSV63966423; called by muse, mutect2, varscan2
- MUC17 | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 331/788 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV60304115; called by muse, mutect2, varscan2
- MYH1 | c.1565C>T p.A522V | Missense Mutation (SNP) | VAF 81/172 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV56857568; called by muse, mutect2, varscan2
- MYH2 | c.1204C>A p.L402I | Missense Mutation (SNP) | VAF 113/291 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.204); catalogued as COSV55448942; called by muse, mutect2, varscan2
- MYH4 | c.5341G>A p.A1781T | Missense Mutation (SNP) | VAF 151/363 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.192); catalogued as rs763267052, COSV55111968; called by muse, mutect2, varscan2
- MYH9 | c.5734C>T p.R1912C | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV53393540; called by muse, mutect2, varscan2
- MYO15A | c.10258T>A p.F3420I | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as CD135884, COSV52766745; called by muse, mutect2, varscan2
- MYO3A | c.1847C>T p.A616V | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.081); catalogued as COSV56350467, COSV99778246; called by muse, mutect2, varscan2
- MYSM1 | c.1719G>T p.E573D | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV68978328; called by muse, mutect2, varscan2
- NAA25 | c.2548G>A p.V850I | Missense Mutation (SNP) | VAF 53/239 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55709422; called by muse, mutect2, varscan2
- NAT1 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 291/623 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs138061602; called by muse, mutect2, varscan2
- NBEAL2 | c.6941T>A p.V2314E | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV52763078; called by muse, mutect2, varscan2
- NEB | c.15614C>T p.P5205L | Missense Mutation (SNP) | VAF 77/173 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51461720; called by muse, mutect2, varscan2
- NEGR1 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 80/189 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60842079; called by muse, mutect2, varscan2
- NELFA | c.1359G>T p.Q453H (on ENST00000542778; = p.Q442H on NM_005663.5) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as COSV56396909; called by muse, mutect2, varscan2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 9/48 reads (19%) | catalogued as rs759081520; called by mutect2, pindel
- NEUROD2 | c.1013C>T p.T338M | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as COSV56911816; called by muse, mutect2, varscan2
- NFKB2 | c.1972C>T p.R658W | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as rs200373995; called by muse, mutect2, varscan2
- NFKBID | c.794G>A p.R265Q (on ENST00000396901; = p.R417Q on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.145); catalogued as rs764013048, COSV61729997; called by muse, mutect2, varscan2
- NFKBIZ | c.1829G>T p.R610L | Missense Mutation (SNP) | VAF 116/284 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.349); catalogued as rs140077856, COSV58202073; called by muse, varscan2
- NIBAN1 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 190/585 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs542303174, COSV62287892; called by muse, mutect2, varscan2
- NIPBL | c.8326del p.I2776Lfs*3 | Frame Shift Del (DEL) | VAF 61/178 reads (34%) | catalogued as rs1157335847; called by mutect2, pindel, varscan2
- NIT1 | c.466G>A p.V156M | Missense Mutation (SNP) | VAF 70/255 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV63502770; called by muse, mutect2, varscan2
- NLGN3 | c.1945C>T p.P649S (on ENST00000358741 / NM_181303.2; = p.P629S on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as COSV62445397; called by muse, mutect2, varscan2
- NME8 | c.15del p.K5Nfs*25 | Frame Shift Del (DEL) | VAF 201/548 reads (37%) | catalogued as COSV99552881; called by mutect2, pindel, varscan2
- NOL6 | c.1477C>T p.P493S | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.9); PolyPhen benign (0.007); catalogued as COSV53046067; called by muse, mutect2, varscan2
- NOL6 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs115821579, COSV53045883; called by muse, mutect2, varscan2
- NOMO2 | c.2212G>A p.V738M | Missense Mutation (SNP) | VAF 114/725 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.212); catalogued as rs759016851, COSV57917140; called by muse, varscan2
- NOX1 | c.498G>T p.E166D | Missense Mutation (SNP) | VAF 257/671 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.433); catalogued as COSV54196780; called by muse, mutect2, varscan2
- NPC1L1 | c.3577G>A p.V1193M | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56930646; called by muse, mutect2, varscan2
- NPR2 | c.2603T>A p.V868D | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61042924; called by muse, mutect2, varscan2
- NRROS | c.737del p.G246Efs*65 | Frame Shift Del (DEL) | VAF 38/101 reads (38%) | catalogued as rs1560056540; called by mutect2, pindel, varscan2
- NUP153 | c.3488C>A p.S1163Y | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV50466975; called by muse, mutect2, varscan2
- NUP188 | c.509T>A p.V170D | Missense Mutation (SNP) | VAF 99/235 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV65365039; called by muse, mutect2, varscan2
- NUTM1 | c.1867T>C p.C623R | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV59219157; called by muse, mutect2, varscan2
- NYNRIN | c.1720C>T p.R574* | Nonsense Mutation (SNP) | VAF 39/99 reads (39%) | catalogued as rs759130124, COSV66845208; called by muse, mutect2, varscan2
- ODF2 | c.1808T>C p.L603P (on ENST00000434106 / NM_153433.2; = p.L579P on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63548801, COSV63548926, COSV63549038; called by muse, mutect2, varscan2
- OLFML1 | c.772C>T p.R258* | Nonsense Mutation (SNP) | VAF 109/215 reads (51%) | catalogued as rs774575686, COSV55076788; called by muse, mutect2, varscan2
- OR1M1 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 152/315 reads (48%) | SIFT tolerated (0.93); PolyPhen benign (0.005); catalogued as rs746194472, COSV70037353; called by muse, mutect2, varscan2
- OR2C3 | c.656A>G p.Y219C | Missense Mutation (SNP) | VAF 61/194 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63576435; called by muse, mutect2, varscan2
- OSBPL7 | c.180G>A p.W60* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as rs948037417, COSV50107343, COSV50116079; called by muse, mutect2
- P2RY10 | c.598A>G p.T200A | Missense Mutation (SNP) | VAF 192/451 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV50686866; called by muse, mutect2, varscan2
- PARP14 | c.3965del p.N1322Ifs*26 | Frame Shift Del (DEL) | VAF 76/168 reads (45%) | catalogued as rs758945932; called by mutect2, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 19/59 reads (32%) | catalogued as CM011452; called by mutect2, pindel, varscan2
- PCDHA9 | c.2114G>A p.C705Y | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV65333135; called by muse, mutect2, varscan2
- PCDHB7 | c.1924G>A p.V642M | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.934); catalogued as rs782005781, COSV50819006; called by muse, mutect2, varscan2
- PCDHB9 | c.770T>C p.V257A | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.253); catalogued as rs1320840104, COSV53384123; called by muse, mutect2
- PCED1B | c.952C>A p.P318T | Missense Mutation (SNP) | VAF 68/174 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV71395656; called by muse, mutect2, varscan2
- PCGF5 | c.8C>T p.T3I | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV60239579; called by muse, mutect2, varscan2
- PCSK5 | c.3401C>T p.A1134V | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.122); catalogued as COSV101377728; called by muse, mutect2, varscan2
- PDE6C | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 78/189 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs750739971, COSV65117298, COSV65117847; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDE8A | c.389T>C p.I130T | Missense Mutation (SNP) | VAF 104/253 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV59640809; called by muse, mutect2, varscan2
- PDE8B | c.1928T>C p.L643S | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.588); catalogued as COSV53732296, COSV53746140; called by muse, mutect2, varscan2
- PDGFD | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.986); catalogued as rs141538106; called by muse, mutect2, varscan2
- PDGFRB | c.1252C>T p.R418* | Nonsense Mutation (SNP) | VAF 48/102 reads (47%) | catalogued as rs1282693161, COSV55801662; called by muse, mutect2, varscan2
- PDS5B | c.4142C>T p.T1381M | Missense Mutation (SNP) | VAF 68/160 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.011); catalogued as rs930374554, COSV59724582; called by muse, mutect2, varscan2
- PDZD3 | c.514G>A p.E172K (on ENST00000531114; = p.E106K on NM_024791.4) | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.188); catalogued as rs979007191, COSV52710038; called by muse, mutect2, varscan2
- PDZD4 | c.752del p.P251Lfs*20 | Frame Shift Del (DEL) | VAF 6/11 reads (55%) | catalogued as COSV99381194; called by mutect2, varscan2
- PEAK1 | c.1004G>A p.S335N | Missense Mutation (SNP) | VAF 176/424 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.628); catalogued as COSV56943676; called by muse, mutect2, varscan2
- PELI3 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1161706622, COSV57857899; called by muse, mutect2, varscan2
- PEX5L | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV55858102; called by muse, mutect2, varscan2
- PFAS | c.1045G>T p.G349C | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58983417; called by muse, mutect2, varscan2
- PFDN1 | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.2); PolyPhen benign (0.048); catalogued as rs757466775, COSV55835387; called by muse, mutect2
- PGBD2 | c.737G>A p.R246K | Missense Mutation (SNP) | VAF 177/585 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV61401184; called by muse, mutect2, varscan2
- PGR | c.2101G>A p.A701T | Missense Mutation (SNP) | VAF 203/464 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54811151; called by muse, mutect2, varscan2
- PHF20 | c.2333G>A p.C778Y | Missense Mutation (SNP) | VAF 165/296 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as COSV64978011; called by muse, mutect2, varscan2
- PIK3C2A | c.2099G>T p.W700L | Missense Mutation (SNP) | VAF 61/137 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56407257; called by muse, mutect2, varscan2
- PIK3C2G | c.2516del p.N839Mfs*16 (on ENST00000676171; = p.N798Mfs*16 on NM_004570.5) | Frame Shift Del (DEL) | VAF 28/73 reads (38%) | catalogued as rs1229278001; called by mutect2, pindel, varscan2
- PIK3CA | c.1075G>C p.G359R | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55968142; called by muse, mutect2, varscan2
- PIWIL1 | c.2042C>T p.A681V | Missense Mutation (SNP) | VAF 102/215 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as rs1349078090, COSV55352254; called by muse, mutect2, varscan2
- PKHD1L1 | c.2899G>T p.E967* | Nonsense Mutation (SNP) | VAF 50/91 reads (55%) | catalogued as COSV65750464; called by muse, mutect2, varscan2
- PKNOX1 | c.879dup p.Q294Tfs*55 | Frame Shift Ins (INS) | VAF 61/152 reads (40%) | catalogued as rs770481809; called by mutect2, pindel, varscan2
- PKP4 | c.497G>A p.S166N | Missense Mutation (SNP) | VAF 96/215 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67679620; called by muse, mutect2, varscan2
- PLA2G4A | c.2236A>G p.K746E | Missense Mutation (SNP) | VAF 65/272 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); catalogued as COSV66557147; called by muse, mutect2, varscan2
- PLA2R1 | c.968A>T p.E323V | Missense Mutation (SNP) | VAF 103/243 reads (42%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.483); catalogued as COSV51787106; called by muse, mutect2, varscan2
- PLCL1 | c.2575C>T p.R859C | Missense Mutation (SNP) | VAF 109/243 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1278187587, COSV70876257; called by muse, mutect2, varscan2
- PLEKHA6 | c.1355G>A p.R452H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs758052468, COSV55340507; called by mutect2, varscan2
- PLEKHG3 | c.1514T>C p.V505A (on ENST00000394691; = p.V561A on NM_001308147.2) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV55984055; called by muse, mutect2, varscan2
- PLEKHH1 | c.3235G>A p.G1079R | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs541575886, COSV61280105, COSV61287981; called by muse, mutect2, varscan2
- PLIN4 | c.1843G>A p.G615S (on ENST00000301286; = p.G630S on NM_001367868.2) | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs367749568; called by muse, varscan2
- PLS3 | c.919A>G p.N307D | Missense Mutation (SNP) | VAF 128/323 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.061); catalogued as COSV56782507; called by muse, mutect2, varscan2
- PML | c.1364A>T p.Y455F | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.023); catalogued as COSV51454697; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1021C>A p.H341N | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV65047221, COSV65049756; called by muse, mutect2, varscan2
- POLR1B | c.1736G>A p.R579H | Missense Mutation (SNP) | VAF 176/384 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs148143581; called by muse, mutect2, varscan2
- POSTN | c.2221C>T p.P741S | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.869); catalogued as COSV65714767; called by muse, mutect2, varscan2
- PPP1R12C | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs749343076, COSV54736930; called by muse, mutect2, varscan2
- PPP2R5D | c.1080G>T p.P360= | Splice Region (SNP) | VAF 27/52 reads (52%) | catalogued as COSV55151648; called by muse, mutect2, varscan2
- PPP6R2 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 235/559 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.25); catalogued as rs769883291, COSV53293195, COSV99324087; called by muse, mutect2, varscan2
- PRDM1 | c.1451C>A p.P484H | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.855); catalogued as COSV64847144; called by muse, mutect2, varscan2
- PRKACG | c.449A>G p.Q150R | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs147576281, COSV55258396; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKCI | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.191); catalogued as rs980860031, COSV55517007; called by muse, mutect2, varscan2
- PRKCQ | c.1025A>G p.Q342R | Missense Mutation (SNP) | VAF 65/204 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.203); catalogued as rs753980026, COSV54119625; called by muse, mutect2, varscan2
- PRND | c.527A>G p.K176R | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as COSV59897397; called by muse, mutect2, varscan2
- PRPF4 | c.977C>T p.A326V (on ENST00000374198 / NM_001322267.2; = p.A327V on NM_004697.5) | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs373783471; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRPF8 | c.1642C>T p.R548W | Missense Mutation (SNP) | VAF 82/203 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV59268094; called by muse, mutect2, varscan2
- PRR14 | c.442G>C p.A148P | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as COSV54913903; called by muse, mutect2, varscan2
- PRRC2C | c.3857G>A p.G1286D (on ENST00000367742; = p.G1284D on NM_015172.4) | Missense Mutation (SNP) | VAF 99/381 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as COSV58913823; called by muse, mutect2, varscan2
- PRRT3 | c.83G>T p.R28M | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.627); catalogued as COSV55978676; called by muse, mutect2, varscan2
- PSME4 | c.702G>T p.W234C | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66367976; called by muse, mutect2, varscan2
- PTCD1 | c.1726A>G p.T576A | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV52867945; called by muse, mutect2, varscan2
- PTPN12 | c.1697_1698del p.V566Efs*11 | Frame Shift Del (DEL) | VAF 91/295 reads (31%) | catalogued as rs1229004721; called by pindel, varscan2
- PTPRM | c.1262A>G p.Y421C | Missense Mutation (SNP) | VAF 86/199 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV59882912; called by muse, mutect2
- PTPRO | c.1088T>A p.I363N | Missense Mutation (SNP) | VAF 101/261 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); catalogued as COSV55523503; called by muse, mutect2, varscan2
- PUM2 | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.702); catalogued as COSV57585546; called by muse, mutect2, varscan2
- R3HDM1 | c.2828C>T p.A943V | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV51528670; called by muse, mutect2, varscan2
- RAB3C | c.541A>G p.K181E | Missense Mutation (SNP) | VAF 154/367 reads (42%) | SIFT tolerated (1); PolyPhen possibly damaging (0.66); catalogued as COSV51442729; called by muse, mutect2, varscan2
- RAPH1 | c.2728C>A p.P910T | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as COSV55589761; called by muse, mutect2, varscan2
- RBBP7 | c.707T>C p.L236P | Missense Mutation (SNP) | VAF 79/207 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV58113454; called by muse, mutect2, varscan2
- RBM5 | c.1679del p.N560Ifs*9 | Frame Shift Del (DEL) | VAF 30/83 reads (36%) | catalogued as COSV61738230; called by mutect2, pindel, varscan2
- RELN | c.8166C>A p.F2722L | Missense Mutation (SNP) | VAF 77/176 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV58987929; called by muse, mutect2, varscan2
- RFC1 | c.1822G>A p.A608T | Missense Mutation (SNP) | VAF 201/460 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV62901229; called by muse, mutect2, varscan2
- RFX7 | c.3781A>G p.S1261G (on ENST00000559447 / NM_001368074.1; = p.S1358G on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV57969124; called by muse, mutect2, varscan2
- RHOBTB2 | c.15G>A p.M5I | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as COSV52573461; called by muse, mutect2, varscan2
- RHPN2 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV54285054; called by muse, mutect2, varscan2
- RIMS2 | c.2965A>G p.M989V (on ENST00000666250 / NM_001348490.2; = p.M797V on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 104/237 reads (44%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as COSV51725840; called by muse, mutect2, varscan2
- RNASE2 | c.160A>G p.M54V | Missense Mutation (SNP) | VAF 176/421 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1204201577, COSV58941587; called by muse, mutect2, varscan2
- RNASE7 | c.337T>C p.S113P | Missense Mutation (SNP) | VAF 298/631 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV53877793; called by mutect2, varscan2
- RNF214 | c.1601C>T p.P534L | Missense Mutation (SNP) | VAF 209/442 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV56121069; called by muse, mutect2, varscan2
- RNF32 | c.209G>A p.C70Y | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV58734956; called by muse, mutect2, varscan2
- ROCK1 | c.3921del p.K1307Nfs*3 | Frame Shift Del (DEL) | VAF 45/214 reads (21%) | catalogued as rs752898741; called by mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 68/83 reads (82%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RRAGB | c.585G>T p.E195D (on ENST00000262850 / NM_016656.4; = p.E167D on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.123); catalogued as COSV53331990; called by muse, mutect2, varscan2
- RSPH6A | c.1309C>T p.P437S | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs1370502414, COSV55575688; called by muse, mutect2, varscan2
- RSPO1 | c.212A>C p.Q71P | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62975369; called by muse, mutect2, varscan2
- S100A2 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs758899452, COSV64185006; called by muse, mutect2, varscan2
- SACS | c.1070G>T p.S357I | Missense Mutation (SNP) | VAF 69/152 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV66547038; called by muse, mutect2, varscan2
- SAP130 | c.2797A>G p.I933V | Missense Mutation (SNP) | VAF 108/230 reads (47%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.007); catalogued as COSV52103256; called by muse, mutect2, varscan2
- SBF1 | c.4834G>A p.V1612M | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.759); catalogued as rs370715026; called by muse, mutect2, varscan2
- SBNO1 | c.3470G>A p.R1157Q (on ENST00000420886; = p.R1156Q on NM_018183.5) | Missense Mutation (SNP) | VAF 160/606 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.089); catalogued as rs146896921, COSV57339356; called by muse, varscan2
- SCAF4 | c.2864C>T p.A955V | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.007); catalogued as rs368484072; called by muse, mutect2, varscan2
- SCARA3 | c.573G>T p.Q191H | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as COSV57271827; called by muse, mutect2, varscan2
- SCML4 | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 70/142 reads (49%) | catalogued as COSV64638183; called by muse, mutect2, varscan2
- SDCBP2 | c.162G>A p.M54I | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV60591106; called by muse, mutect2, varscan2
- SEMA6D | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 112/263 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV60372008; called by muse, mutect2, varscan2
- SERHL2 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs1430309221, COSV59670254; called by mutect2, varscan2
- SGO2 | c.1929del p.G644Vfs*18 | Frame Shift Del (DEL) | VAF 229/355 reads (65%) | catalogued as rs1260834379; called by mutect2, pindel, varscan2
- SGSM1 | c.1339G>A p.A447T | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.054); catalogued as rs1341422504, COSV68513890; called by muse, mutect2, varscan2
- SH2B3 | c.1712A>G p.Q571R | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57986834; called by muse, mutect2, varscan2
- SHROOM3 | c.778T>C p.Y260H | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56039831; called by muse, mutect2, varscan2
- SI | c.2350G>A p.A784T | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.122); catalogued as COSV52301992; called by muse, mutect2, varscan2
- SIDT1 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 185/422 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs376848215; called by muse, mutect2
- SIPA1L3 | c.2461C>T p.R821C | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs367900084; called by muse, mutect2, varscan2
- SLC10A6 | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 120/261 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.164); catalogued as rs763476428, COSV56723519; called by muse, mutect2, varscan2
- SLC25A38 | c.94C>A p.L32M | Missense Mutation (SNP) | VAF 108/262 reads (41%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.517); catalogued as COSV56195573; called by muse, mutect2, varscan2
- SLC26A6 | c.1618del p.V540* | Frame Shift Del (DEL) | VAF 21/61 reads (34%) | catalogued as rs780816364, COSV56576227; called by mutect2, pindel, varscan2
- SLC26A9 | c.498G>T p.E166D | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61605648; called by muse, mutect2, varscan2
- SLC30A1 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV65361372; called by muse, mutect2
- SLC4A10 | c.2103A>G p.S701= (on ENST00000446997 / NM_001354461.2; = p.S671= on NM_022058.4 and 5 other RefSeq transcripts) | Splice Region (SNP) | VAF 12/31 reads (39%) | catalogued as COSV55800942; called by muse, mutect2
- SLC4A2 | c.2158C>A p.L720M | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59659416; called by muse, mutect2, varscan2
- SLC4A3 | c.1823G>A p.S608N | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56097771; called by muse, mutect2, varscan2
- SLC4A3 | c.3047G>A p.R1016Q | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56095748, COSV56097783; called by muse, mutect2, varscan2
- SLC6A7 | c.832del p.Q278Sfs*82 | Frame Shift Del (DEL) | VAF 38/120 reads (32%) | catalogued as COSV57939345; called by mutect2, pindel, varscan2
- SMARCA4 | c.4232G>A p.R1411Q | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.709); catalogued as rs886054155, COSV60809425, COSV60809995; ClinVar: uncertain significance; called by muse, mutect2
- SMG1 | c.9310C>A p.L3104I | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.967); catalogued as COSV67174928; called by muse, mutect2, varscan2
- SMG6 | c.889T>C p.S297P | Missense Mutation (SNP) | VAF 70/170 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV53976771; called by muse, mutect2
- SMG7 | c.2288C>T p.A763V | Missense Mutation (SNP) | VAF 169/571 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.153); catalogued as rs1313777617, COSV61634473; called by muse, mutect2, varscan2
- SNX27 | c.1426C>T p.R476* | Nonsense Mutation (SNP) | VAF 38/479 reads (8%) | catalogued as rs1346732190, COSV64327645; called by muse, mutect2
- SON | c.5806C>T p.R1936C | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV51671160; called by muse, mutect2, varscan2
- SPEF2 | c.3263T>C p.F1088S | Missense Mutation (SNP) | VAF 195/486 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV61553929; called by muse, mutect2, varscan2
- SPN | c.742C>A p.P248T | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.496); catalogued as COSV64070013, COSV64071146; called by muse, mutect2, varscan2
- SPTB | c.5320G>T p.G1774W | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV67635178; called by muse, mutect2, varscan2
- SREK1IP1 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 31/111 reads (28%) | catalogued as rs767854725, COSV72486467; called by muse, mutect2, varscan2
- SRPK3 | c.1634T>C p.M545T | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54210196; called by muse, mutect2, varscan2
- STAT1 | c.1445G>T p.R482M | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV63117539; called by muse, mutect2, varscan2
- STIM2 | c.1547G>A p.R516H | Missense Mutation (SNP) | VAF 191/465 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs140734561; called by muse, mutect2, varscan2
- STK10 | c.911G>T p.R304L | Missense Mutation (SNP) | VAF 110/230 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.266); catalogued as COSV51579281; called by muse, mutect2, varscan2
- STRIP1 | c.1675C>G p.Q559E | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.349); catalogued as rs760940524, COSV63931262; called by muse, mutect2, varscan2
- SV2A | c.412del p.E138Rfs*39 | Frame Shift Del (DEL) | VAF 54/311 reads (17%) | catalogued as rs1553764068; called by mutect2, pindel, varscan2
- SVIL | c.5586del p.M1863Wfs*44 (on ENST00000355867 / NM_021738.3; = p.M1437Wfs*44 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs770033147; called by mutect2, varscan2
- SYNJ1 | c.1625G>A p.R542H | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.988); catalogued as rs756697570, COSV59157104; ClinVar: uncertain significance; called by muse, mutect2
- TAF1 | c.964C>T p.R322C (on ENST00000373790 / NM_138923.4; = p.R343C on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 174/429 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52114812; called by muse, mutect2, varscan2
- TAS2R8 | c.67G>T p.G23W | Missense Mutation (SNP) | VAF 75/242 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53690850; called by muse, mutect2, varscan2
- TBC1D31 | c.1893del p.H632Tfs*8 | Frame Shift Del (DEL) | VAF 64/140 reads (46%) | catalogued as rs768246273; called by mutect2, varscan2
- TBRG4 | c.1084C>T p.Q362* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as COSV51834400; called by muse, mutect2
- TBX19 | c.99del p.G34Afs*28 | Frame Shift Del (DEL) | VAF 80/314 reads (25%) | catalogued as COSV100892340; called by mutect2, pindel, varscan2
- TEAD2 | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs774036088, COSV60545310; called by muse, mutect2, varscan2
- TECPR2 | c.2956G>A p.V986I | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as rs751307750, COSV63970365; called by muse, mutect2, varscan2
- TECTA | c.6274G>T p.G2092* | Nonsense Mutation (SNP) | VAF 91/202 reads (45%) | catalogued as COSV50810328; called by muse, mutect2, varscan2
- TFDP1 | c.779C>A p.P260H | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV64742801; called by muse, mutect2, varscan2
- TFE3 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV59949362; called by muse, mutect2, varscan2
- TIAM2 | c.406C>T p.H136Y | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.015); catalogued as rs1442303338, COSV59704652; called by muse, mutect2, varscan2
- TIE1 | c.1942dup p.R648Pfs*52 | Frame Shift Ins (INS) | VAF 47/130 reads (36%) | catalogued as rs749393189; called by pindel, varscan2
- TIPIN | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV56021122; called by muse, mutect2, varscan2
- TLR3 | c.580T>G p.F194V | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as COSV57170494; called by muse, mutect2, varscan2
- TLR4 | c.1484T>C p.L495P (on ENST00000355622 / NM_138554.5; = p.L455P on NM_003266.4) | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62923013; called by muse, mutect2, varscan2
- TMC4 | c.330G>T p.R110S (on ENST00000617472 / NM_001145303.3; = p.R104S on NM_144686.4) | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as COSV55477721; called by muse, mutect2, varscan2
- TMEM143 | c.886G>A p.V296M | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs895232661, COSV53158995; called by muse, mutect2, varscan2
- TMEM181 | c.169C>T p.H57Y | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.093); catalogued as COSV65566033; called by muse, mutect2
- TMEM211 | c.427T>C p.Y143H (on ENST00000423535; = p.Y72H on NM_001001663.3) | Missense Mutation (SNP) | VAF 145/341 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1465175196, COSV66954465; called by muse, mutect2, varscan2
- TMEM254 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 100/246 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs748149784, COSV64846123; called by muse, mutect2, varscan2
- TMEM39B | c.952T>C p.W318R | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1395117042, COSV60381424; called by muse, mutect2, varscan2
- TMEM60 | c.231del p.A78Pfs*11 | Frame Shift Del (DEL) | VAF 78/200 reads (39%) | catalogued as rs749773249; called by mutect2, varscan2
- TMEM74B | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV67892356; called by muse, mutect2, varscan2
- TMTC3 | c.1554dup p.Y519Ifs*8 | Frame Shift Ins (INS) | VAF 59/170 reads (35%) | catalogued as rs746894544; called by mutect2, pindel, varscan2
- TNIP3 | c.614A>G p.Q205R | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV50254508; called by muse, mutect2, varscan2
- TNK2 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767496703, COSV57370788; called by muse, mutect2, varscan2
- TNNT2 | c.616C>T p.R206W (on ENST00000236918; = p.R203W on NM_000364.4) | Missense Mutation (SNP) | VAF 57/182 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs730881106, COSV52665431; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TNPO1 | c.2336C>T p.T779I | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV61524095; called by muse, mutect2, varscan2
- TRANK1 | c.3047C>T p.A1016V | Missense Mutation (SNP) | VAF 187/420 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs547852895, COSV57139664; called by muse, mutect2, varscan2
- TRIM23 | c.1018C>A p.L340I | Missense Mutation (SNP) | VAF 69/208 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.098); catalogued as COSV51554743; called by muse, mutect2, varscan2
- TRIOBP | c.6608A>G p.Q2203R (on ENST00000644935 / NM_001039141.3; = p.Q490R on NM_007032.5) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV60373853; called by muse, mutect2, varscan2
- TSC2 | c.767G>A p.C256Y | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54780679; called by muse, mutect2, varscan2
- TSNARE1 | c.81G>C p.Q27H | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV56184395; called by muse, mutect2, varscan2
- TTC16 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); catalogued as COSV58854472; called by muse, mutect2, varscan2
- TTC3 | c.2334del p.E779Kfs*5 | Frame Shift Del (DEL) | VAF 124/294 reads (42%) | catalogued as rs756650873; called by mutect2, varscan2
- TTC8 | c.452T>C p.L151P (on ENST00000338104 / NM_001288781.1; = p.L161P on NM_144596.4) | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV57630746; called by muse, mutect2, varscan2
- TTI1 | c.2770del p.L924Wfs*37 | Frame Shift Del (DEL) | VAF 37/96 reads (39%) | catalogued as rs760253164; called by mutect2, pindel, varscan2
- TTK | c.2320del p.R774Gfs*36 | Frame Shift Del (DEL) | VAF 50/128 reads (39%) | catalogued as rs1215363692; called by mutect2, pindel, varscan2
- TUBA3E | c.376-1G>A p.X126_splice | Splice Site (SNP) | VAF 40/97 reads (41%) | catalogued as COSV56059979; called by muse, mutect2, varscan2
- TUT1 | c.427G>C p.A143P | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV53472089; called by muse, mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 72/156 reads (46%) | catalogued as rs760251146; called by mutect2, varscan2
- TYK2 | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs760895143, COSV53392290; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBAP1 | c.355C>A p.P119T | Missense Mutation (SNP) | VAF 149/383 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52662005; called by muse, mutect2, varscan2
- UBN1 | c.2833G>A p.A945T | Missense Mutation (SNP) | VAF 100/214 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV52173261; called by muse, mutect2, varscan2
- UBR4 | c.7751G>A p.R2584H | Missense Mutation (SNP) | VAF 238/562 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1408873535, COSV64394617; called by muse, mutect2, varscan2
- UGGT1 | c.491T>C p.L164P | Missense Mutation (SNP) | VAF 62/113 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV52141964; called by muse, mutect2, varscan2
- UGGT2 | c.2889G>A p.M963I | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV65079746; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3996del p.I1333Sfs*20 | Frame Shift Del (DEL) | VAF 59/161 reads (37%) | catalogued as COSV51954201; called by mutect2, pindel, varscan2
- ULK2 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 186/457 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV64448696; called by muse, mutect2
- UMOD | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.773); catalogued as rs1350479147, COSV56780078; called by muse, mutect2, varscan2
- UPRT | c.8C>T p.T3M | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); catalogued as rs1270700952, COSV64912197; called by muse, mutect2, varscan2
- USF3 | c.1217C>A p.S406Y | Missense Mutation (SNP) | VAF 49/295 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57077675; called by muse, mutect2, varscan2
- USP16 | c.2099T>G p.F700C | Missense Mutation (SNP) | VAF 68/122 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100538112, COSV57628048; called by muse, mutect2, varscan2
- USP42 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs766801728, COSV60359320; called by muse, mutect2, varscan2
- USP9X | c.3305C>T p.A1102V | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.31); catalogued as COSV61075418; called by muse, varscan2
- VAV2 | c.1432G>A p.G478S (on ENST00000371850 / NM_001134398.2; = p.G468S on NM_003371.4) | Missense Mutation (SNP) | VAF 9/9 reads (100%) | SIFT tolerated (0.27); PolyPhen probably damaging (1); catalogued as rs186434110; called by muse, mutect2, varscan2
- VEGFA | c.545+1G>A p.X182_splice (on ENST00000523873 / NM_001171623.1; = p.X362_splice on NM_001025366.3) | Splice Site (SNP) | VAF 23/73 reads (32%) | catalogued as COSV57879989; called by muse, mutect2, varscan2
- VPS50 | c.1962del p.F654Lfs*19 | Frame Shift Del (DEL) | VAF 20/49 reads (41%) | catalogued as rs771091392; called by mutect2, pindel, varscan2
- WASHC5 | c.2933C>T p.A978V | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.416); catalogued as COSV59200692; called by muse, mutect2, varscan2
- WDR19 | c.1940A>G p.D647G | Missense Mutation (SNP) | VAF 177/420 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV56470376; called by muse, mutect2, varscan2
- WDR24 | c.1262C>T p.A421V (on ENST00000248142; = p.A291V on NM_032259.4) | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); catalogued as COSV50205265; called by muse, mutect2, varscan2
- WDR88 | c.1312G>A p.V438M | Missense Mutation (SNP) | VAF 70/152 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as rs556151988, COSV63451530; called by muse, mutect2, varscan2
- WRAP53 | c.1619C>T p.T540M | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs375718073, COSV56834959; called by muse, mutect2, varscan2
- WWP2 | c.1838C>T p.A613V | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63127958; called by muse, mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 28/97 reads (29%) | catalogued as rs779864368; called by mutect2, pindel, varscan2
- ZBED8 | c.887G>T p.R296M | Missense Mutation (SNP) | VAF 143/327 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.394); catalogued as COSV68825063; called by muse, mutect2, varscan2
- ZBTB20 | c.881G>A p.R294H (on ENST00000474710 / NM_001164342.2; = p.R221H on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.749); catalogued as COSV61870617; called by muse, mutect2, varscan2
- ZC3H4 | c.1895T>C p.M632T | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as COSV53417392; called by muse, mutect2, varscan2
- ZCCHC14 | c.184G>A p.V62I (on ENST00000268616; = p.V199I on NM_015144.3) | Missense Mutation (SNP) | VAF 154/354 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV51890593; called by muse, varscan2
- ZEB2 | c.1850A>G p.H617R | Missense Mutation (SNP) | VAF 117/241 reads (49%) | SIFT tolerated (0.52); PolyPhen benign (0.028); catalogued as rs1448603705, COSV57966795; called by muse, mutect2, varscan2
- ZFHX3 | c.6385G>A p.A2129T | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.578); catalogued as COSV51737210; called by muse, mutect2, varscan2
- ZFYVE21 | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as rs374319040; called by muse, mutect2, varscan2
- ZIC3 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV54972605; called by muse, mutect2, varscan2
- ZKSCAN5 | c.2072dup p.N691Kfs*5 | Frame Shift Ins (INS) | VAF 104/251 reads (41%) | catalogued as rs556762260; called by mutect2, varscan2
- ZNF112 | c.1112G>A p.S371N (on ENST00000337401 / NM_001083335.2; = p.S365N on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV61622194; called by muse, mutect2, varscan2
- ZNF142 | c.1040G>T p.R347L (on ENST00000411696 / NM_001379660.1; = p.R147L on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 152/345 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV68745886; called by muse, mutect2, varscan2
- ZNF148 | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 74/183 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62307660; called by muse, varscan2
- ZNF263 | c.1754G>A p.R585Q | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs781606939, COSV54595998; called by muse, mutect2, varscan2
- ZNF275 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 249/565 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs782151498, COSV64705472; called by muse, mutect2, varscan2
- ZNF407 | c.4915G>T p.E1639* | Nonsense Mutation (SNP) | VAF 52/162 reads (32%) | catalogued as COSV55271049; called by muse, mutect2, varscan2
- ZNF519 | c.1007C>T p.T336I | Missense Mutation (SNP) | VAF 185/491 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.068); catalogued as COSV73913642; called by muse, mutect2, varscan2
- ZNF532 | c.107A>G p.D36G | Missense Mutation (SNP) | VAF 123/294 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV60175938; called by muse, mutect2, varscan2
- ZNF536 | c.3548T>A p.V1183D | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV62834629; called by muse, mutect2, varscan2
- ZNF555 | c.459G>A p.M153I | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs771709144, COSV62074100; called by muse, mutect2, varscan2
- ZNF599 | c.266C>T p.T89I | Missense Mutation (SNP) | VAF 68/147 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.348); catalogued as COSV61397528; called by muse, mutect2, varscan2
- ZNF646 | c.5254C>T p.R1752W | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1465832074, COSV54926769; called by muse, mutect2, varscan2
- ZNF697 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 8/14 reads (57%) | catalogued as COSV70284349; called by muse, mutect2, varscan2
- ZNF74 | c.545G>T p.R182M | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.43); catalogued as COSV62624332; called by muse, mutect2, varscan2
- ZNF862 | c.2498G>A p.R833H | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.143); catalogued as rs1339850472, COSV56226323; called by muse, mutect2, varscan2
- ZSWIM4 | c.2443C>T p.R815C | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.176); catalogued as rs565047636, COSV54325892; called by muse, mutect2, varscan2
- ZXDA | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62388945; called by muse, mutect2, varscan2
- AARS1 | c.1759dup p.D587Gfs*8 | Frame Shift Ins (INS) | VAF 6/59 reads (10%) | called by mutect2, pindel
- ACLY | c.933del p.S312Afs*16 | Frame Shift Del (DEL) | VAF 30/297 reads (10%) | called by mutect2, pindel, varscan2
- ADNP | c.528_529del p.Y177* | Frame Shift Del (DEL) | VAF 157/404 reads (39%) | called by mutect2, pindel, varscan2
- AFAP1 | c.970del p.I324Sfs*31 | Frame Shift Del (DEL) | VAF 34/98 reads (35%) | called by mutect2, varscan2
- AKAP9 | c.5890del p.T1964Lfs*13 (on ENST00000359028; = p.T1932Lfs*13 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 69/198 reads (35%) | called by mutect2, pindel, varscan2
- AMZ2 | c.628del p.Y210Ifs*9 | Frame Shift Del (DEL) | VAF 34/136 reads (25%) | called by mutect2, pindel, varscan2
- ANKZF1 | c.566del p.P189Qfs*40 | Frame Shift Del (DEL) | VAF 76/247 reads (31%) | called by mutect2, pindel, varscan2
- AQP4 | c.920del p.G307Efs*19 | Frame Shift Del (DEL) | VAF 127/351 reads (36%) | called by mutect2, pindel, varscan2
- ARHGEF6 | c.85_87del p.E29del | In Frame Del (DEL) | VAF 158/458 reads (34%) | called by pindel, varscan2
- ARID1A | c.1650del p.Y551Tfs*68 | Frame Shift Del (DEL) | VAF 201/531 reads (38%) | called by mutect2, pindel, varscan2
- ART5 | c.692del p.L231Wfs*14 | Frame Shift Del (DEL) | VAF 68/146 reads (47%) | called by mutect2, pindel, varscan2
- ATAT1 | c.899del p.P300Hfs*31 (on ENST00000376485; = p.P300Hfs*65 on NM_024909.4) | Frame Shift Del (DEL) | VAF 66/196 reads (34%) | called by mutect2, pindel, varscan2
- BPTF | c.1726del p.T576Qfs*141 | Frame Shift Del (DEL) | VAF 140/376 reads (37%) | called by mutect2, pindel, varscan2
- C14orf39 | c.737del p.N246Ifs*8 | Frame Shift Del (DEL) | VAF 34/92 reads (37%) | called by mutect2, pindel, varscan2
- C1orf35 | c.580_581del p.K194Efs*19 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | called by mutect2, pindel, varscan2
- CAD | c.3512del p.P1171Hfs*40 | Frame Shift Del (DEL) | VAF 25/72 reads (35%) | called by mutect2, pindel, varscan2
- CCDC148 | c.1260del p.K420Nfs*15 | Frame Shift Del (DEL) | VAF 24/55 reads (44%) | called by mutect2, varscan2
- CIC | c.4462del p.Q1488Rfs*22 | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | called by mutect2, pindel, varscan2
- CLASRP | c.284del p.P95Lfs*81 | Frame Shift Del (DEL) | VAF 25/196 reads (13%) | called by mutect2, varscan2
- CLEC16A | c.1832del p.L611Wfs*11 | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | called by mutect2, pindel, varscan2
- CTSW | c.1003del p.A335Pfs*34 | Frame Shift Del (DEL) | VAF 34/94 reads (36%) | called by mutect2, pindel, varscan2
- DDX42 | c.586del p.I196Sfs*29 | Frame Shift Del (DEL) | VAF 78/235 reads (33%) | called by mutect2, pindel, varscan2
- DNAJC12 | c.327del p.D110Tfs*2 | Frame Shift Del (DEL) | VAF 92/235 reads (39%) | called by mutect2, pindel, varscan2
- DSCAML1 | c.3821del p.P1274Lfs*7 (on ENST00000321322; = p.P1214Lfs*7 on NM_020693.4) | Frame Shift Del (DEL) | VAF 74/229 reads (32%) | called by mutect2, pindel, varscan2
- EEF1A1 | c.382_383del p.S128Qfs*25 | Frame Shift Del (DEL) | VAF 36/126 reads (29%) | called by pindel, varscan2
- ELK3 | c.525del p.V176Wfs*7 | Frame Shift Del (DEL) | VAF 31/82 reads (38%) | called by mutect2, pindel, varscan2
- EML5 | c.2588del p.N863Mfs*4 | Frame Shift Del (DEL) | VAF 297/805 reads (37%) | called by mutect2, pindel, varscan2
- EP400 | c.3282del p.F1094Lfs*4 | Frame Shift Del (DEL) | VAF 56/138 reads (41%) | called by mutect2, pindel, varscan2
- EPHA2 | c.1379del p.P460Rfs*33 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | called by mutect2, pindel, varscan2
- ERBB4 | c.2045dup p.K683Efs*35 | Frame Shift Ins (INS) | VAF 84/277 reads (30%) | called by pindel, varscan2
- EXOSC9 | c.234del p.F78Lfs*23 | Frame Shift Del (DEL) | VAF 42/118 reads (36%) | called by mutect2, varscan2
- FAM193A | c.834del p.R279Gfs*33 | Frame Shift Del (DEL) | VAF 65/190 reads (34%) | called by mutect2, pindel, varscan2
- FOXM1 | c.2008del p.E671Nfs*12 | Frame Shift Del (DEL) | VAF 39/102 reads (38%) | called by mutect2, pindel, varscan2
- FRYL | c.6013del p.W2005Gfs*2 | Frame Shift Del (DEL) | VAF 74/207 reads (36%) | called by mutect2, pindel, varscan2
- GABRG1 | c.1086del p.G363Efs*10 | Frame Shift Del (DEL) | VAF 26/171 reads (15%) | called by mutect2, pindel, varscan2
- GMPPB | c.260-3del | Splice Region (DEL) | VAF 7/17 reads (41%) | called by mutect2, varscan2
- GTF3C4 | c.1602del p.F534Lfs*4 | Frame Shift Del (DEL) | VAF 72/217 reads (33%) | called by mutect2, pindel, varscan2
- HJV | c.779dup p.S261Ifs*9 (on ENST00000336751 / NM_213653.4; = p.S148Ifs*9 on NM_145277.5) | Frame Shift Ins (INS) | VAF 67/267 reads (25%) | called by mutect2, pindel, varscan2
- HNRNPA3 | c.387dup p.V130Cfs*5 | Frame Shift Ins (INS) | VAF 31/91 reads (34%) | called by mutect2, pindel, varscan2
- ICE1 | c.2878_2881del p.S960Lfs*12 | Frame Shift Del (DEL) | VAF 61/144 reads (42%) | called by mutect2, pindel, varscan2
- ILF3 | c.1201del p.Q401Rfs*3 | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | called by mutect2, pindel, varscan2
- IRX3 | c.706del p.E236Rfs*24 | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | called by mutect2, pindel, varscan2
- JAK1 | c.407del p.N136Mfs*32 | Frame Shift Del (DEL) | VAF 80/218 reads (37%) | called by pindel, varscan2
- KMT2D | c.10394del p.G3465Dfs*37 | Frame Shift Del (DEL) | VAF 34/92 reads (37%) | called by mutect2, pindel
- LRRC4 | c.649dup p.L217Pfs*16 | Frame Shift Ins (INS) | VAF 11/29 reads (38%) | called by mutect2, pindel, varscan2
- LTN1 | c.3169dup p.M1057Nfs*6 | Frame Shift Ins (INS) | VAF 28/120 reads (23%) | called by mutect2, varscan2
- MAGI1 | c.1991del p.G664Vfs*5 | Frame Shift Del (DEL) | VAF 93/250 reads (37%) | called by mutect2, pindel, varscan2
- MED26 | c.538del p.L180Sfs*241 | Frame Shift Del (DEL) | VAF 17/34 reads (50%) | called by mutect2, pindel, varscan2
- MEPCE | c.940del p.Q314Nfs*124 | Frame Shift Del (DEL) | VAF 27/62 reads (44%) | called by mutect2, pindel, varscan2
- MIS18BP1 | c.3294_3295+9del p.X1098_splice | Splice Site (DEL) | VAF 35/134 reads (26%) | called by mutect2, pindel, varscan2
- MKLN1 | c.1551_1552del p.R517Sfs*4 | Frame Shift Del (DEL) | VAF 26/221 reads (12%) | called by pindel, varscan2
- MROH2B | c.2071del p.S691Lfs*6 | Frame Shift Del (DEL) | VAF 77/209 reads (37%) | called by mutect2, pindel, varscan2
- NELL2 | c.18dup p.L7Tfs*25 | Frame Shift Ins (INS) | VAF 43/123 reads (35%) | called by mutect2, pindel, varscan2
- NEXN | c.717dup p.E240Rfs*13 | Frame Shift Ins (INS) | VAF 130/335 reads (39%) | called by mutect2, varscan2
- NR2E3 | c.1004dup p.L336Pfs*5 | Frame Shift Ins (INS) | VAF 8/26 reads (31%) | called by mutect2, pindel, varscan2
- OR2G6 | c.236dup p.Q80Tfs*8 | Frame Shift Ins (INS) | VAF 121/554 reads (22%) | called by mutect2, pindel, varscan2
- OSBPL1A | c.2378dup p.N793Kfs*2 (on ENST00000319481 / NM_080597.4; = p.N280Kfs*2 on NM_018030.4) | Frame Shift Ins (INS) | VAF 91/226 reads (40%) | called by mutect2, varscan2
- OTUD6B | c.171del p.E58Kfs*13 | Frame Shift Del (DEL) | VAF 78/272 reads (29%) | called by pindel, varscan2
- OVOL2 | c.747del p.K249Nfs*10 | Frame Shift Del (DEL) | VAF 22/61 reads (36%) | called by mutect2, pindel, varscan2
- P2RY6 | c.402del p.W135Gfs*12 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel, varscan2
- PAN3 | c.1238dup p.L413Ffs*35 | Frame Shift Ins (INS) | VAF 81/212 reads (38%) | called by mutect2, pindel, varscan2
- PCDHA5 | c.584del p.L195* | Frame Shift Del (DEL) | VAF 39/94 reads (41%) | called by mutect2, pindel, varscan2
- PLK2 | c.1004_1008+15delinsGCAGGTTGGTGCACTATC p.X335_splice | Splice Site (DEL) | VAF 9/76 reads (12%) | called by pindel, varscan2*
- PLXNA2 | c.92del p.P31Qfs*23 | Frame Shift Del (DEL) | VAF 41/161 reads (25%) | called by mutect2, pindel, varscan2
- POGLUT2 | c.1071del p.F357Lfs*10 | Frame Shift Del (DEL) | VAF 41/102 reads (40%) | called by mutect2, pindel, varscan2
- POLE | c.1101dup p.D368* | Frame Shift Ins (INS) | VAF 14/131 reads (11%) | called by mutect2, varscan2
- PRICKLE2 | c.2557dup p.Q853Pfs*12 (on ENST00000295902; = p.Q797Pfs*12 on NM_198859.4) | Frame Shift Ins (INS) | VAF 47/133 reads (35%) | called by mutect2, pindel, varscan2
- PRICKLE4 | c.211del p.V71* (on ENST00000359201; = p.V111* on NM_013397.6) | Frame Shift Del (DEL) | VAF 42/112 reads (38%) | called by mutect2, pindel, varscan2
- RAB14 | c.469del p.T157Rfs*5 | Frame Shift Del (DEL) | VAF 25/74 reads (34%) | called by mutect2, pindel, varscan2
- RAB23 | c.140del p.L47Wfs*14 | Frame Shift Del (DEL) | VAF 93/243 reads (38%) | called by mutect2, pindel, varscan2
- RAB3GAP2 | c.2795_2797del p.E932del | In Frame Del (DEL) | VAF 102/415 reads (25%) | called by mutect2, pindel, varscan2
- RAD54L2 | c.1409del p.N470Tfs*10 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by mutect2, pindel, varscan2
- RBBP6 | c.3625del p.I1209Sfs*47 | Frame Shift Del (DEL) | VAF 92/267 reads (34%) | called by mutect2, pindel, varscan2
- RNF17 | c.704del p.N235Ifs*3 | Frame Shift Del (DEL) | VAF 62/120 reads (52%) | called by mutect2, varscan2
- RPGRIP1L | c.2460dup p.D821* | Frame Shift Ins (INS) | VAF 148/448 reads (33%) | called by mutect2, pindel, varscan2
- RXFP2 | c.1709del p.N570Mfs*26 | Frame Shift Del (DEL) | VAF 58/167 reads (35%) | called by mutect2, pindel, varscan2
- SEL1L3 | c.1873del p.L625Wfs*36 | Frame Shift Del (DEL) | VAF 21/172 reads (12%) | called by mutect2, pindel, varscan2
- SERPINI1 | c.845_846del p.S282Cfs*20 | Frame Shift Del (DEL) | VAF 50/166 reads (30%) | called by pindel, varscan2
- SH3KBP1 | c.1720del p.L574Cfs*39 | Frame Shift Del (DEL) | VAF 14/102 reads (14%) | called by mutect2, pindel, varscan2
- SH3PXD2B | c.419del p.K140Rfs*21 | Frame Shift Del (DEL) | VAF 7/81 reads (9%) | called by mutect2, pindel
- SIPA1L1 | c.220dup p.M74Nfs*21 | Frame Shift Ins (INS) | VAF 166/522 reads (32%) | called by mutect2, pindel, varscan2
- SLC35A2 | c.795dup p.G266Wfs*28 | Frame Shift Ins (INS) | VAF 12/23 reads (52%) | called by mutect2, varscan2
- TBC1D10A | c.518del p.G173Afs*11 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, pindel, varscan2
- TFB2M | c.48del p.L17Wfs*10 | Frame Shift Del (DEL) | VAF 31/87 reads (36%) | called by mutect2, pindel, varscan2
- TLE1 | c.1917_1941delinsCGA p.V640Efs*40 | Frame Shift Del (DEL) | VAF 38/78 reads (49%) | called by pindel, varscan2*
- TNFRSF1A | c.843del p.T282Pfs*70 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | called by mutect2, pindel, varscan2
- TNNC2 | c.113dup p.E39Gfs*27 | Frame Shift Ins (INS) | VAF 40/114 reads (35%) | called by mutect2, pindel, varscan2
- TUBGCP5 | c.1592C>T p.A531V | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- UBR4 | c.1517dup p.A507Cfs*20 | Frame Shift Ins (INS) | VAF 69/181 reads (38%) | called by mutect2, pindel, varscan2
- USP45 | c.603del p.F201Lfs*17 | Frame Shift Del (DEL) | VAF 42/124 reads (34%) | called by pindel, varscan2
- USP7 | c.340del p.S114Afs*2 | Frame Shift Del (DEL) | VAF 102/224 reads (46%) | called by mutect2, pindel, varscan2
- WAPL | c.904_909dup p.T302_K303dup | In Frame Ins (INS) | VAF 150/398 reads (38%) | called by mutect2, varscan2
- ZBED4 | c.1034del p.G345Afs*33 | Frame Shift Del (DEL) | VAF 58/146 reads (40%) | called by mutect2, pindel, varscan2
- ZNF142 | c.2358_2360del p.T787del (on ENST00000411696 / NM_001379660.1; = p.T587del on NM_001105537.4 and 5 other RefSeq transcripts) | In Frame Del (DEL) | VAF 26/74 reads (35%) | called by pindel, varscan2
- ZNF263 | c.550del p.Q184Rfs*3 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | called by mutect2, pindel
- ZNF608 | c.3494del p.N1165Tfs*5 | Frame Shift Del (DEL) | VAF 61/267 reads (23%) | called by mutect2, pindel, varscan2
- ZNF862 | c.2825del p.P942Hfs*3 | Frame Shift Del (DEL) | VAF 40/121 reads (33%) | called by mutect2, pindel, varscan2
- ABHD6 | c.588C>T p.A196= | Silent (SNP) | VAF 85/213 reads (40%) | catalogued as rs759397255, COSV55908101; called by muse, mutect2, varscan2
- ABL1 | c.2229G>A p.T743= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as rs373223198; called by muse, mutect2, varscan2
- AC004922.1 | c.1767C>T p.S589= | Silent (SNP) | VAF 13/20 reads (65%) | catalogued as COSV53165006; called by muse, mutect2, varscan2
- ACADL | c.1173A>G p.G391= | Silent (SNP) | VAF 50/118 reads (42%) | catalogued as COSV52055501; called by muse, mutect2, varscan2
- ADCY7 | c.2310C>T p.C770= | Silent (SNP) | VAF 27/52 reads (52%) | catalogued as rs200556322, COSV54271201; called by muse, mutect2, varscan2
- AGPAT5 | c.294C>T p.D98= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as COSV53449378; called by muse, mutect2, varscan2
- AHCTF1 | c.5487A>G p.R1829= (on ENST00000366508; = p.R1803= on NM_015446.5) | Silent (SNP) | VAF 65/284 reads (23%) | catalogued as COSV58256026; called by muse, mutect2, varscan2
- AHCYL1 | c.1212C>T p.I404= | Silent (SNP) | VAF 57/132 reads (43%) | catalogued as rs371217627; called by muse, mutect2, varscan2
- AKAP12 | c.4080C>T p.H1360= | Silent (SNP) | VAF 192/454 reads (42%) | catalogued as rs374901951; called by muse, mutect2, varscan2
- ANKRD33 | c.303G>A p.T101= (on ENST00000340970 / NM_001304459.2; = p.T226= on NM_182608.4) | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as rs751378413, COSV56608201; called by muse, mutect2, varscan2
- ANO8 | c.1161C>T p.S387= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs201773203; called by muse, mutect2, varscan2
- ARFGEF2 | c.3042G>C p.L1014= | Silent (SNP) | VAF 75/194 reads (39%) | catalogued as rs747306818, COSV64215362; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARHGAP21 | c.369A>G p.R123= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as rs1404907236, COSV64546334; called by muse, mutect2, varscan2
- ASIC3 | c.1221C>T p.N407= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs767611755, COSV52526014; called by muse, mutect2, varscan2
- ATG4B | c.564C>A p.P188= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV60353227; called by muse, mutect2, varscan2
- ATP11C | c.2073C>T p.C691= | Silent (SNP) | VAF 164/473 reads (35%) | catalogued as COSV59574807; called by muse, mutect2, varscan2
- BCOR | c.4039C>T p.L1347= (on ENST00000378444 / NM_001123385.2; = p.L1313= on NM_017745.6) | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as COSV60710459; called by muse, mutect2, varscan2
- BEND2 | c.657G>A p.Q219= | Silent (SNP) | VAF 254/564 reads (45%) | catalogued as COSV66217375; called by muse, mutect2, varscan2
- BIRC6 | c.7095G>A p.T2365= | Silent (SNP) | VAF 84/169 reads (50%) | catalogued as rs371974273, COSV70206443; called by muse, mutect2, varscan2
- BRINP2 | c.870C>T p.C290= | Silent (SNP) | VAF 39/109 reads (36%) | catalogued as rs750223104, COSV64180479; called by muse, mutect2, varscan2
- BTN2A2 | c.561T>C p.G187= | Silent (SNP) | VAF 99/257 reads (39%) | catalogued as rs1468868366, COSV61858763; called by muse, mutect2, varscan2
- C7orf26 | c.420G>A p.T140= | Silent (SNP) | VAF 60/132 reads (45%) | catalogued as rs575087048, COSV60420645; called by muse, mutect2, varscan2
- CACNA1E | c.3843C>T p.C1281= | Silent (SNP) | VAF 59/214 reads (28%) | catalogued as rs373094161; called by muse, mutect2, varscan2
- CAMK4 | c.753C>T p.F251= | Silent (SNP) | VAF 29/243 reads (12%) | catalogued as COSV56683781; called by muse, mutect2, varscan2
- CATSPERG | c.2436G>A p.K812= | Silent (SNP) | VAF 55/145 reads (38%) | catalogued as COSV53054084; called by muse, mutect2, varscan2
- CBLN2 | c.294G>A p.T98= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs769764685, COSV54052680; called by muse, mutect2, varscan2
- CCL3L3 | c.54C>T p.C18= | Silent (SNP) | VAF 22/63 reads (35%) | called by muse, mutect2, varscan2
- CD96 | c.90A>G p.E30= | Silent (SNP) | VAF 114/279 reads (41%) | catalogued as COSV51923340; called by muse, mutect2, varscan2
- CDHR2 | c.1938G>C p.G646= | Silent (SNP) | VAF 31/65 reads (48%) | catalogued as COSV56145780, COSV99991649; called by muse, mutect2, varscan2
- CDK13 | c.4206T>C p.S1402= | Silent (SNP) | VAF 105/256 reads (41%) | catalogued as COSV51706733; called by muse, mutect2, varscan2
- CENPJ | c.1605G>A p.R535= | Silent (SNP) | VAF 111/242 reads (46%) | catalogued as rs1261312114, COSV67883767; called by muse, mutect2, varscan2
- CFAP44 | c.885C>T p.H295= | Silent (SNP) | VAF 148/376 reads (39%) | catalogued as COSV55616035; called by muse, varscan2
- CHD6 | c.5124T>C p.Y1708= | Silent (SNP) | VAF 97/238 reads (41%) | catalogued as rs369081071, COSV64694674; called by muse, mutect2, varscan2
- CHL1 | c.2652C>A p.A884= (on ENST00000397491 / NM_001253387.1; = p.A900= on NM_006614.4) | Silent (SNP) | VAF 42/98 reads (43%) | catalogued as rs755805594, COSV56607140; called by muse, mutect2, varscan2
- CLASP1 | c.4092A>G p.A1364= | Silent (SNP) | VAF 62/140 reads (44%) | catalogued as COSV55341530; called by muse, mutect2, varscan2
- CLCA4 | c.1221A>G p.E407= | Silent (SNP) | VAF 118/296 reads (40%) | catalogued as COSV55371351; called by muse, mutect2, varscan2
- CLDN23 | c.273G>A p.T91= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs1268180780, COSV67731704; called by muse, mutect2, varscan2
- CNTN3 | c.622C>T p.L208= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as COSV55185065; called by muse, mutect2, varscan2
- COL7A1 | c.5883G>A p.E1961= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as COSV60403522; called by muse, mutect2, varscan2
- CTNS | c.648G>A p.T216= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs772591288, COSV50444624; called by muse, mutect2
- CXXC1 | c.1347C>G p.R449= | Silent (SNP) | VAF 51/336 reads (15%) | catalogued as COSV53277010; called by muse, mutect2, varscan2
- CYP26A1 | c.834G>A p.S278= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs779220881, COSV56420070; called by muse, mutect2
- DCST1 | c.154C>T p.L52= | Silent (SNP) | VAF 55/162 reads (34%) | catalogued as rs751009674, COSV55054833; called by muse, mutect2, varscan2
- DDAH2 | c.177G>A p.Q59= | Silent (SNP) | VAF 6/108 reads (6%) | catalogued as COSV65384447; called by muse, mutect2
- DEPDC5 | c.2289G>A p.V763= (on ENST00000400246; = p.V832= on NM_014662.5) | Silent (SNP) | VAF 54/175 reads (31%) | catalogued as COSV56711341; called by muse, mutect2, varscan2
- DNAH2 | c.279G>A p.V93= | Silent (SNP) | VAF 58/114 reads (51%) | catalogued as COSV50021061; called by muse, mutect2
- DNM1L | c.1452T>C p.H484= | Silent (SNP) | VAF 110/279 reads (39%) | catalogued as rs1345420824, COSV56778168; called by muse, mutect2, varscan2
- DOCK6 | c.5583C>T p.R1861= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs768282386, COSV53922973; called by muse, mutect2, varscan2
- DSCAM | c.5901C>T p.A1967= | Silent (SNP) | VAF 58/132 reads (44%) | catalogued as rs772161625, COSV68021646, COSV68030295; called by muse, mutect2, varscan2
- DYNC2H1 | c.207T>C p.G69= | Silent (SNP) | VAF 35/96 reads (36%) | catalogued as COSV62087121; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1575C>T p.I525= (on ENST00000361735 / NM_015935.5; = p.I439= on NM_014955.3) | Silent (SNP) | VAF 32/400 reads (8%) | catalogued as rs774592620, COSV62282419; called by muse, mutect2
- ERV3-1 | c.1782A>G p.L594= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as COSV99276167; called by muse, mutect2
- EXOSC1 | c.468C>A p.A156= | Silent (SNP) | VAF 79/181 reads (44%) | catalogued as COSV58356332; called by muse, mutect2, varscan2
- FAM131A | c.669C>T p.C223= (on ENST00000310585; = p.C254= on NM_144635.5) | Silent (SNP) | VAF 45/103 reads (44%) | catalogued as rs760655033, COSV55601072; called by muse, mutect2, varscan2
- FANCE | c.324G>A p.S108= | Silent (SNP) | VAF 37/71 reads (52%) | catalogued as rs762826105, COSV57691140; called by muse, mutect2, varscan2
- FHOD3 | c.672C>T p.N224= | Silent (SNP) | VAF 62/156 reads (40%) | catalogued as rs763044140, COSV57189419; called by muse, mutect2, varscan2
- FNDC1 | c.1983C>T p.G661= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV51948166; called by muse, mutect2, varscan2
- FRMD4A | c.2016G>A p.P672= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as rs531553216, COSV62269456; called by muse, mutect2, varscan2
- G2E3 | c.81C>T p.Y27= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs148066743; called by muse, mutect2, varscan2
- GNAZ | c.115C>T p.L39= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as COSV50742057; called by muse, mutect2, varscan2
- GNB3 | c.525G>A p.Q175= | Silent (SNP) | VAF 80/144 reads (56%) | catalogued as COSV51834454; called by muse, mutect2, varscan2
- GPR20 | c.324G>A p.T108= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs373756599; called by muse, mutect2, varscan2
- GPR3 | c.666C>T p.R222= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as COSV64995226; called by muse, mutect2, varscan2
- GPSM2 | c.1578T>C p.T526= | Silent (SNP) | VAF 122/244 reads (50%) | catalogued as rs780101621, COSV99915633; called by mutect2, varscan2
- GUCY2F | c.2004T>C p.H668= | Silent (SNP) | VAF 152/374 reads (41%) | catalogued as COSV54309010; called by muse, mutect2, varscan2
- H2AZ1 | c.93C>T p.G31= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as COSV56455974; called by muse, mutect2, varscan2
- HEATR6 | c.2262A>G p.A754= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV51749259; called by muse, mutect2, varscan2
- HERC2 | c.11343G>A p.L3781= | Silent (SNP) | VAF 94/268 reads (35%) | catalogued as rs751057853, COSV55351331; called by muse, mutect2, varscan2
- HGD | c.1083A>G p.G361= | Silent (SNP) | VAF 110/287 reads (38%) | catalogued as COSV52197241; called by mutect2, varscan2
- HIC2 | c.172C>A p.R58= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as COSV68041790, COSV68042922; called by muse, mutect2, varscan2
- HOXB3 | c.519C>T p.G173= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as COSV61145443; called by muse, varscan2
- HR | c.3033C>T p.A1011= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs760560680, COSV57194836; called by muse, mutect2, varscan2
- HS3ST3A1 | c.768G>A p.T256= | Silent (SNP) | VAF 82/210 reads (39%) | catalogued as rs768704913, COSV52375124; called by muse, mutect2, varscan2
- IGF2R | c.4275C>T p.A1425= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as rs749413548, COSV63632941; called by muse, mutect2, varscan2
- IGLV2-33 | c.141C>T p.D47= | Silent (SNP) | VAF 74/612 reads (12%) | catalogued as rs370439730; called by muse, mutect2, varscan2
- INPP4B | c.315T>C p.Y105= | Silent (SNP) | VAF 67/141 reads (48%) | catalogued as rs1562021693, COSV53746757; called by muse, mutect2, varscan2
- INTS6L | c.1935C>T p.G645= | Silent (SNP) | VAF 328/832 reads (39%) | catalogued as rs782259666, COSV66084536; called by muse, mutect2, varscan2
- IRF2BPL | c.2055C>G p.P685= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV53149080; called by muse, mutect2, varscan2
- IRF8 | c.540G>A p.Q180= | Silent (SNP) | VAF 32/61 reads (52%) | catalogued as COSV51900677; called by muse, mutect2, varscan2
- IRS1 | c.1170C>T p.V390= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV59340226; called by muse, mutect2, varscan2
- ITPRIP | c.1200C>T p.P400= | Silent (SNP) | VAF 45/100 reads (45%) | catalogued as rs751680766, COSV53393281; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1467C>T p.F489= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs370671042; called by muse, mutect2, varscan2
- KCTD4 | c.684C>T p.I228= | Silent (SNP) | VAF 101/250 reads (40%) | catalogued as COSV61243003; called by muse, mutect2, varscan2
- KDELR2 | c.432C>T p.A144= | Silent (SNP) | VAF 117/215 reads (54%) | catalogued as rs147548462; called by muse, mutect2, varscan2
- KRT8 | c.1407T>C p.R469= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV53179379; called by muse, mutect2, varscan2
- LAMB3 | c.387C>T p.A129= | Silent (SNP) | VAF 33/101 reads (33%) | catalogued as rs374988953; ClinVar: likely benign; called by muse, mutect2, varscan2
- LCE2B | c.60T>C p.C20= | Silent (SNP) | VAF 243/855 reads (28%) | catalogued as COSV64227888; called by muse, mutect2, varscan2
- LCTL | c.819C>T p.P273= | Silent (SNP) | VAF 75/407 reads (18%) | catalogued as COSV58421621, COSV58423132; called by muse, mutect2, varscan2
- LHX2 | c.741C>T p.N247= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs755198475, COSV65319178; called by muse, mutect2, varscan2
- LOXL3 | c.55C>T p.L19= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs768888102, COSV51209604; called by muse, mutect2, varscan2
- LRRC39 | c.771G>A p.L257= | Silent (SNP) | VAF 42/110 reads (38%) | catalogued as COSV61584152; called by muse, mutect2, varscan2
- LRRIQ1 | c.993G>A p.K331= | Silent (SNP) | VAF 45/105 reads (43%) | catalogued as COSV67839138; called by muse, mutect2, varscan2
- LUZP1 | c.1371C>T p.P457= | Silent (SNP) | VAF 269/662 reads (41%) | catalogued as rs144635559; called by muse, mutect2, varscan2
- MAGEE1 | c.1437C>T p.S479= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as COSV63912220; called by muse, mutect2, varscan2
- MAPKBP1 | c.388C>T p.L130= | Silent (SNP) | VAF 45/94 reads (48%) | catalogued as COSV52967182; called by muse, mutect2, varscan2
- MBD6 | c.1785T>C p.P595= | Silent (SNP) | VAF 31/73 reads (42%) | catalogued as rs760510889, COSV63076497; called by muse, mutect2, varscan2
- MED14 | c.4023G>A p.T1341= | Silent (SNP) | VAF 58/125 reads (46%) | catalogued as rs780193067, COSV61358668; called by muse, mutect2, varscan2
- MEIOB | c.1317A>G p.Q439= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV58055915; called by muse, mutect2, varscan2
- MFAP3L | c.423C>T p.R141= | Silent (SNP) | VAF 104/245 reads (42%) | catalogued as rs754281347, COSV64372009; called by muse, mutect2, varscan2
- MKRN2 | c.99G>A p.P33= | Silent (SNP) | VAF 46/120 reads (38%) | catalogued as rs748561804, COSV50105679; called by muse, mutect2, varscan2
- MUC16 | c.26430C>A p.A8810= | Silent (SNP) | VAF 180/376 reads (48%) | catalogued as rs1268733597, COSV67495609; called by muse, mutect2, varscan2
- MUC5AC | c.13896C>A p.A4632= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV100611615; called by muse, mutect2, varscan2
- MYBBP1A | c.3804C>T p.P1268= | Silent (SNP) | VAF 50/105 reads (48%) | catalogued as rs1233689517, COSV54604779; called by muse, mutect2, varscan2
- NAIF1 | c.330C>T p.G110= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as rs1179613021, COSV66092534; called by muse, mutect2
- NBPF11 | c.2421T>C p.V807= | Silent (SNP) | VAF 375/1443 reads (26%) | called by muse, mutect2, varscan2
- NCAM1 | c.1383C>T p.S461= (on ENST00000316851 / NM_181351.5; = p.S451= on NM_000615.7) | Silent (SNP) | VAF 10/150 reads (7%) | catalogued as rs781787182, COSV57525386; called by muse, mutect2
- NEIL3 | c.288C>T p.F96= | Silent (SNP) | VAF 44/89 reads (49%) | catalogued as rs532020443, COSV52811926; called by muse, mutect2, varscan2
- NKRF | c.1368C>T p.N456= | Silent (SNP) | VAF 105/223 reads (47%) | catalogued as rs1488682913, COSV58661328; called by muse, mutect2, varscan2
- NOD1 | c.1692G>A p.P564= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as rs1467583590, COSV56112516; called by muse, mutect2, varscan2
- NOMO1 | c.2994C>T p.D998= | Silent (SNP) | VAF 55/337 reads (16%) | catalogued as rs749796273, COSV55061530; called by muse, mutect2, varscan2
- NOS2 | c.2575C>T p.L859= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV58227640; called by muse, mutect2, varscan2
- NOTCH4 | c.3441A>G p.S1147= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV66684020; called by muse, mutect2, varscan2
96 further variants in this file (0 protein-altering or splice-affecting, 75 silent, 21 other) are not listed here.
